Somatic mutation profile of tumor specimen TCGA-AA-A010-01A (aliquot TCGA-AA-A010-01A-01W-A00E-09) from TCGA case TCGA-AA-A010, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Transverse colon; AJCC pathologic stage: Stage IIB; Age at diagnosis: 46.3 years (16,922 days).
Specimen TCGA-AA-A010-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 367541d6-9c42-409a-9069-1c702954bede.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-A010-10A (Blood Derived Normal), aliquot TCGA-AA-A010-10A-01D-A17O-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0575be03-6c30-490b-b98c-57a2dbf5a5b6

The open-access MAF lists 7,937 somatic variants for this specimen: 6,245 protein-altering or splice-affecting, 1,520 silent, 172 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5,440, Silent 1,520, Nonsense Mutation 620, Splice Site 91, Intron 78, Splice Region 44, RNA 43, Frame Shift Del 22, 3'UTR 19, Frame Shift Ins 19, 5'UTR 14, 3'Flank 11.

Variants (750 of 7,937; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1690C>T p.R564* | Nonsense Mutation (SNP) | VAF 94/252 reads (37%) | hotspot (GDC flag); catalogued as rs137854574, CM920035, COSV57321509; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 82/226 reads (36%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.5161C>T p.R1721* | Nonsense Mutation (SNP) | VAF 104/328 reads (32%) | hotspot (GDC flag); catalogued as COSV61371260; called by muse, mutect2, varscan2
- ARID2 | c.940C>T p.R314C | Missense Mutation (SNP) | VAF 101/259 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1424958105, COSV57595631, COSV57607050; called by muse, mutect2, varscan2
- ATM | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 59/166 reads (36%) | hotspot (GDC flag); catalogued as rs772821016, CM030188, CS991299, COSV53725394; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP2A1 | c.2366C>T p.P789L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs121918115, CM001614, COSV62868414; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRCA2 | c.8991T>G p.Y2997* | Nonsense Mutation (SNP) | VAF 59/155 reads (38%) | catalogued as rs397508028, CM070045, COSV66447999; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CC2D2A | c.3850C>T p.R1284C | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779823379, CM120107, COSV67502170; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CRB1 | c.2290C>T p.R764C | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs62635654, CM992151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EDNRB | c.1027C>T p.R343* (on ENST00000377211 / NM_001201397.1; = p.R253* on NM_000115.5) | Nonsense Mutation (SNP) | VAF 85/296 reads (29%) | catalogued as rs104894390, CM993141, COSV57518833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EIF2B5 | c.607C>T p.R203C (on ENST00000647909; = p.R195C on NM_003907.3) | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs113994055, CM031178, COSV56603661; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ERBB3 | c.985A>G p.K329E | Missense Mutation (SNP) | VAF 47/165 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV57246521; called by muse, mutect2, varscan2
- ETV6 | c.1105C>T p.R369W | Missense Mutation (SNP) | VAF 43/102 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1511682, COSV56765384, COSV56765583; called by muse, mutect2, varscan2
- F9 | c.1150C>T p.R384* | Nonsense Mutation (SNP) | VAF 85/155 reads (55%) | catalogued as rs137852261, CM940671, COSV54378604; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FZD6 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 92/240 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs981045005, CM132595, COSV100708516; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- GNAQ | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 50/122 reads (41%) | hotspot (GDC flag); catalogued as COSV54106777, COSV99680195; called by muse, mutect2, varscan2
- HADHA | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 49/123 reads (40%) | catalogued as rs137852775, CM983469, COSV66106265; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ITGB6 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs140015315, CM142981; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MITF | c.646C>T p.R216* (on ENST00000448226 / NM_006722.3; = p.R110* on NM_000248.4) | Nonsense Mutation (SNP) | VAF 21/62 reads (34%) | catalogued as rs1553702006, CM132683, COSV58829776; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.2836G>T p.E946* | Nonsense Mutation (SNP) | VAF 146/340 reads (43%) | catalogued as rs1558666905, COSV52274084; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH6 | c.3964G>T p.E1322* | Nonsense Mutation (SNP) | VAF 98/286 reads (34%) | catalogued as rs1553333707, CM1412053, COSV52274101; ClinVar: pathogenic; called by muse, varscan2
- NIPBL | c.2500C>T p.R834* | Nonsense Mutation (SNP) | VAF 107/303 reads (35%) | catalogued as rs587783907, CM062926, COSV56941928; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NT5C2 | c.430C>T p.R144* | Nonsense Mutation (SNP) | VAF 42/119 reads (35%) | catalogued as rs764453448, COSV58414684; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1042C>T p.R348* (on ENST00000521381 / NM_181523.3; = p.R78* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 39/54 reads (72%) | hotspot (GDC flag); catalogued as rs1057520690, COSV57123475; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PKD2 | c.2407C>T p.R803* | Nonsense Mutation (SNP) | VAF 60/141 reads (43%) | catalogued as rs778235410, CM012179, COSV52936442; ClinVar: pathogenic; called by muse, mutect2, varscan2
- POU3F4 | c.499C>T p.R167* | Nonsense Mutation (SNP) | VAF 13/21 reads (62%) | catalogued as rs111033345, CM109199, COSV64537699; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 320/427 reads (75%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RSBN1L | c.1294T>G p.L432V | Missense Mutation (SNP) | VAF 95/263 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.607); catalogued as rs202084915; called by muse, mutect2
- RSPH3 | c.595C>T p.R199* (on ENST00000252655; = p.R57* on NM_031924.8) | Nonsense Mutation (SNP) | VAF 37/80 reads (46%) | catalogued as rs760122351, COSV51921181; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TGFBR1 | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 163/527 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs111854391, CM061221, COSV66624834; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TGFBR2 | c.1489C>T p.R497* | Nonsense Mutation (SNP) | VAF 123/157 reads (78%) | catalogued as rs863223852, CM063204, COSV55443474; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 22/61 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138729528, CM011013, CM118880, COSV52688031, COSV52713177, COSV52717943, COSV53372849; ClinVar: uncertain significance / likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- TP63 | c.1780C>T p.R594* | Nonsense Mutation (SNP) | VAF 20/61 reads (33%) | catalogued as rs900140738, COSV53196111; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TPM2 | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.534); catalogued as rs1563929454, COSV61404711; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TTN | c.78181C>T p.R26061* (on ENST00000591111; = p.R18637* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 97/268 reads (36%) | catalogued as rs1559314812, COSV59879573; ClinVar: pathogenic; called by muse, mutect2, varscan2
- XPO1 | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 45/138 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV68944577, COSV68946813; called by muse, mutect2, varscan2
- A2ML1 | c.4034G>A p.R1345Q | Missense Mutation (SNP) | VAF 60/204 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs1388303934, COSV55285428; called by muse, mutect2
- AACS | c.701A>C p.K234T | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as rs552840406; called by muse, mutect2, varscan2
- AACS | c.973G>T p.D325Y | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55534374; called by muse, mutect2
- AAGAB | c.463G>T p.E155* | Nonsense Mutation (SNP) | VAF 143/382 reads (37%) | catalogued as COSV56015883; called by muse, mutect2, varscan2
- AARS1 | c.1904G>T p.R635I | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV55746064, COSV55748707; called by muse, mutect2, varscan2
- AARS2 | c.2755C>T p.P919S | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.038); catalogued as rs1350653756, COSV55113196; called by mutect2, varscan2
- AASS | c.2563A>C p.T855P | Missense Mutation (SNP) | VAF 212/514 reads (41%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.633); catalogued as COSV62788770; called by muse, mutect2, varscan2
- AASS | c.1144G>T p.D382Y | Missense Mutation (SNP) | VAF 82/245 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as COSV62788783; called by muse, mutect2, varscan2
- AATF | c.1546C>T p.R516W | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199725061; called by muse, mutect2, varscan2
- ABAT | c.941A>G p.D314G | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV51620102; called by muse, mutect2, varscan2
- ABCA10 | c.3448G>A p.V1150I | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.76); PolyPhen benign (0.027); catalogued as rs755234389, COSV52218031; called by muse, mutect2, varscan2
- ABCA10 | c.1010A>C p.K337T | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.104); catalogued as COSV52218056; called by muse, varscan2
- ABCA12 | c.6137T>C p.V2046A (on ENST00000272895 / NM_173076.3; = p.V1728A on NM_015657.3) | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV55948917; called by muse, mutect2, varscan2
- ABCA12 | c.3080G>T p.S1027I (on ENST00000272895 / NM_173076.3; = p.S709I on NM_015657.3) | Missense Mutation (SNP) | VAF 136/355 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV55948926; called by muse, mutect2, varscan2
- ABCA12 | c.719A>C p.K240T | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.015); catalogued as COSV55948937, COSV55964636; called by muse, mutect2, varscan2
- ABCA13 | c.2445A>C p.E815D | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as COSV70025716; called by muse, mutect2, varscan2
- ABCA13 | c.8026G>T p.E2676* | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | catalogued as rs375142489; called by muse, mutect2, varscan2
- ABCA13 | c.12128G>A p.R4043H | Missense Mutation (SNP) | VAF 84/206 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs766530816, COSV71283192; called by muse, mutect2, varscan2
- ABCA5 | c.4214G>T p.S1405I | Missense Mutation (SNP) | VAF 63/177 reads (36%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.581); catalogued as COSV67015681; called by muse, varscan2
- ABCA5 | c.4143G>T p.Q1381H | Missense Mutation (SNP) | VAF 47/149 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67015685; called by muse, varscan2
- ABCA5 | c.1666A>C p.K556Q | Missense Mutation (SNP) | VAF 59/170 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.134); catalogued as COSV67015686; called by muse, mutect2, varscan2
- ABCA5 | c.1493G>T p.R498I | Missense Mutation (SNP) | VAF 83/229 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV67015688; called by muse, mutect2, varscan2
- ABCA7 | c.5196G>T p.K1732N | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV54023939; called by muse, mutect2, varscan2
- ABCA8 | c.4607A>C p.D1536A | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as COSV52193919; called by muse, mutect2, varscan2
- ABCA8 | c.2117T>G p.L706R | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52193929; called by muse, mutect2, varscan2
- ABCA9 | c.3955G>T p.G1319C | Missense Mutation (SNP) | VAF 86/216 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60620080; called by muse, mutect2, varscan2
- ABCA9 | c.1785G>T p.E595D | Missense Mutation (SNP) | VAF 75/184 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.03); catalogued as COSV60620093; called by muse, mutect2, varscan2
- ABCA9 | c.1415C>A p.S472Y | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV60620107; called by muse, mutect2, varscan2
- ABCB1 | c.1092A>C p.E364D | Missense Mutation (SNP) | VAF 114/289 reads (39%) | SIFT tolerated (0.51); PolyPhen benign (0.034); catalogued as COSV55944896; called by muse, mutect2, varscan2
- ABCB11 | c.2276C>A p.S759Y | Missense Mutation (SNP) | VAF 62/156 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); catalogued as COSV55585031; called by muse, mutect2, varscan2
- ABCB11 | c.1643T>G p.F548C | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as CM067624, COSV55585046; called by muse, mutect2
- ABCB11 | c.1057G>T p.E353* | Nonsense Mutation (SNP) | VAF 47/121 reads (39%) | catalogued as COSV55585060; called by muse, mutect2, varscan2
- ABCB4 | c.3749T>C p.V1250A (on ENST00000265723 / NM_018849.3; = p.V1243A on NM_000443.4) | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV55931856; called by muse, mutect2, varscan2
- ABCB4 | c.2953G>T p.V985L | Missense Mutation (SNP) | VAF 11/293 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs948902384; called by muse, mutect2
- ABCB5 | c.1175C>A p.S392Y | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as rs1238145045, COSV51702857; called by muse, mutect2, varscan2
- ABCB5 | c.2412A>C p.Q804H (on ENST00000404938 / NM_001163941.2; = p.Q359H on NM_178559.6) | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as COSV51702867; called by muse, mutect2, varscan2
- ABCB8 | c.2113G>A p.E705K (on ENST00000297504 / NM_001282291.2; = p.E688K on NM_007188.5) | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.17); PolyPhen benign (0.079); catalogued as rs1325175450, COSV52502181; called by muse, mutect2, varscan2
- ABCC1 | c.1502G>A p.R501Q | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60679996; called by muse, mutect2, varscan2
- ABCC1 | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as rs751292519, COSV60680004; called by muse, mutect2, varscan2
- ABCC10 | c.2057T>G p.F686C (on ENST00000372530 / NM_001198934.2; = p.F658C on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1288961399, COSV55084286; called by muse, mutect2
- ABCC10 | c.4148C>A p.S1383Y (on ENST00000372530 / NM_001198934.2; = p.S1355Y on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55084299; called by muse, mutect2, varscan2
- ABCC12 | c.3853G>A p.A1285T | Missense Mutation (SNP) | VAF 39/108 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs771541274, COSV60911476; called by muse, varscan2
- ABCC12 | c.2245G>T p.E749* | Nonsense Mutation (SNP) | VAF 48/173 reads (28%) | catalogued as COSV60911484; called by muse, mutect2, varscan2
- ABCC2 | c.1579A>C p.N527H | Missense Mutation (SNP) | VAF 128/298 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV64984483; called by muse, mutect2, varscan2
- ABCC2 | c.2827G>A p.E943K | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs574920702, COSV64984487; called by muse, mutect2, varscan2
- ABCC4 | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 66/141 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as COSV65309555; called by muse, mutect2, varscan2
- ABCC6 | c.703G>T p.D235Y | Missense Mutation (SNP) | VAF 47/150 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52741167; called by muse, mutect2, varscan2
- ABCC9 | c.4157G>A p.R1386H | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730880035, COSV53962305; ClinVar: uncertain significance; called by muse, varscan2
- ABCC9 | c.3017C>T p.S1006L | Missense Mutation (SNP) | VAF 64/190 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.298); catalogued as rs1200576081, COSV53962315; called by muse, mutect2, varscan2
- ABCC9 | c.1874C>T p.S625L | Missense Mutation (SNP) | VAF 79/207 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as rs75460545, COSV53962326; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCD1 | c.1024T>C p.S342P | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.944); catalogued as CM950046, COSV54383395; called by muse, mutect2, varscan2
- ABCG2 | c.1957A>G p.K653E | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372911459; called by muse, mutect2, varscan2
- ABCG8 | c.260G>A p.G87D | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.548); catalogued as COSV55390520; called by muse, mutect2, varscan2
- ABHD12 | c.349C>A p.P117T | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); catalogued as COSV59283653; called by muse, mutect2, varscan2
- ABI3BP | c.315G>T p.K105N | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV52527951; called by muse, mutect2, varscan2
- ABRAXAS1 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 63/150 reads (42%) | catalogued as COSV58948039; called by muse, mutect2, varscan2
- ABRAXAS2 | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 23/62 reads (37%) | catalogued as COSV53715950; called by muse, mutect2, varscan2
- ABTB1 | c.806A>T p.N269I (on ENST00000232744 / NM_172027.3; = p.N127I on NM_032548.3) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV99229639; called by muse, mutect2
- AC004922.1 | c.8T>C p.L3P | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as COSV53555442; called by muse, mutect2, varscan2
- AC011462.1 | c.358G>T p.G120C | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV54195456; called by muse, mutect2, varscan2
- AC134980.2 | c.664C>A p.L222I | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as COSV60906563; called by mutect2, varscan2
- ACACA | c.4381C>T p.R1461C | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs769240769; called by muse, mutect2, varscan2
- ACACA | c.3145G>A p.A1049T | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs758519292; called by muse, mutect2, varscan2
- ACACB | c.1978G>A p.E660K | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757955756, COSV58127896, COSV58128229; called by muse, mutect2
- ACAD9 | c.231C>A p.F77L | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs748758547, COSV58306406; called by muse, mutect2, varscan2
- ACADM | c.274C>A p.P92T | Missense Mutation (SNP) | VAF 53/113 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63719653; called by muse, mutect2, varscan2
- ACAN | c.5159C>A p.S1720Y | Missense Mutation (SNP) | VAF 28/91 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61355589; called by muse, mutect2, varscan2
- ACAP2 | c.191G>A p.R64Q | Missense Mutation (SNP) | VAF 77/193 reads (40%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.91); catalogued as rs1405156868, COSV58749193; called by muse, mutect2, varscan2
- ACAT2 | c.1087C>A p.L363I | Missense Mutation (SNP) | VAF 40/125 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); catalogued as COSV100364906, COSV58457385; called by muse, mutect2, varscan2
- ACCS | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 65/203 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as rs373138553, COSV99772928; called by muse, mutect2, varscan2
- ACCSL | c.1603G>T p.E535* | Nonsense Mutation (SNP) | VAF 25/76 reads (33%) | catalogued as COSV66579952; called by muse, mutect2, varscan2
- ACE2 | c.1882C>T p.L628F | Missense Mutation (SNP) | VAF 76/117 reads (65%) | SIFT tolerated (0.05); PolyPhen benign (0.086); catalogued as COSV53023553; called by muse, mutect2, varscan2
- ACMSD | c.749A>G p.D250G | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV51605451; called by muse, mutect2, varscan2
- ACP1 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.536); catalogued as rs769115575, COSV55242247; called by muse, mutect2, varscan2
- ACP1 | c.356G>A p.S119N | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs1396382259, COSV55242262; called by muse, mutect2, varscan2
- ACRV1 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 177/454 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs768673984, COSV59754494; called by muse, mutect2, varscan2
- ACSBG1 | c.1406G>A p.R469H | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs748664490, COSV51903267, COSV99357652, COSV99357780; called by muse, mutect2, varscan2
- ACSBG1 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV51903277; called by muse, mutect2
- ACSBG1 | c.98T>A p.I33N | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV51903286; called by muse, mutect2, varscan2
- ACSBG2 | c.2001A>C p.*667Cext*3 | Nonstop Mutation (SNP) | VAF 14/61 reads (23%) | catalogued as COSV53122878; called by muse, mutect2, varscan2
- ACSL3 | c.364A>C p.K122Q | Missense Mutation (SNP) | VAF 67/185 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV62480716; called by muse, mutect2, varscan2
- ACSL3 | c.1087A>C p.K363Q | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV62480729; called by muse, mutect2, varscan2
- ACSM1 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 62/162 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs146842441, COSV54632756, COSV54637011; called by muse, mutect2, varscan2
- ACSM4 | c.1156G>T p.E386* | Nonsense Mutation (SNP) | VAF 27/63 reads (43%) | catalogued as COSV68066592; called by muse, mutect2, varscan2
- ACTL7B | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1263764064, COSV65926824; called by muse, mutect2, varscan2
- ACTL7B | c.536C>T p.T179M | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV65926826; called by muse, mutect2, varscan2
- ACTN1 | c.1495C>T p.R499W | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs372651589; called by muse, mutect2, varscan2
- ACTR3 | c.841A>C p.I281L | Missense Mutation (SNP) | VAF 66/173 reads (38%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as COSV54298217; called by muse, mutect2, varscan2
- ACVR1B | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 61/139 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs765649298, COSV57774835; called by muse, mutect2, varscan2
- ACVR1B | c.1273G>T p.E425* | Nonsense Mutation (SNP) | VAF 28/74 reads (38%) | catalogued as COSV57779659; called by muse, varscan2
- ACVR1B | c.1330C>T p.R444* | Nonsense Mutation (SNP) | VAF 26/77 reads (34%) | catalogued as COSV57774850; called by muse, varscan2
- ACVR2A | c.687G>A p.W229* | Nonsense Mutation (SNP) | VAF 36/99 reads (36%) | catalogued as COSV54018935; called by muse, mutect2, varscan2
- ACVR2B | c.1158G>T p.M386I | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as COSV61701055; called by muse, mutect2, varscan2
- ADAD1 | c.624G>T p.K208N | Missense Mutation (SNP) | VAF 70/200 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.358); catalogued as COSV56641390, COSV99635265, COSV99636245; called by muse, mutect2, varscan2
- ADAD1 | c.905A>C p.K302T | Missense Mutation (SNP) | VAF 84/224 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV56641400; called by muse, mutect2, varscan2
- ADAM11 | c.1531G>A p.D511N | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52344281; called by muse, mutect2
- ADAM12 | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 11/32 reads (34%) | catalogued as COSV64102398; called by muse, mutect2, varscan2
- ADAM15 | c.514C>A p.L172I | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as COSV55056362; called by muse, mutect2, varscan2
- ADAM17 | c.1615A>G p.N539D | Missense Mutation (SNP) | VAF 172/395 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV60397511; called by muse, mutect2, varscan2
- ADAM18 | c.527A>C p.K176T | Missense Mutation (SNP) | VAF 130/375 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV55843562; called by muse, mutect2, varscan2
- ADAM2 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 89/260 reads (34%) | SIFT tolerated (0.65); PolyPhen benign (0.055); catalogued as rs1486484687, COSV55858669; called by muse, mutect2, varscan2
- ADAM32 | c.1724G>A p.R575Q | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.169); catalogued as rs536001133, COSV65947053; called by muse, mutect2, varscan2
- ADAM7 | c.1210T>G p.F404V | Missense Mutation (SNP) | VAF 45/81 reads (56%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV51534811, COSV51537473; called by muse, mutect2, varscan2
- ADAM7 | c.1507A>G p.K503E | Missense Mutation (SNP) | VAF 56/143 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.266); catalogued as COSV51534837; called by muse, varscan2
- ADAMTS10 | c.2335C>T p.R779* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as COSV54351845; called by muse, mutect2
- ADAMTS12 | c.4762C>T p.L1588F | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV61255253; called by muse, varscan2
- ADAMTS12 | c.4515A>C p.K1505N | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.19); catalogued as COSV61255266; called by muse, mutect2, varscan2
- ADAMTS12 | c.4159C>T p.R1387C | Missense Mutation (SNP) | VAF 84/217 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs771662441, COSV61254693; called by muse, mutect2, varscan2
- ADAMTS16 | c.2449G>A p.D817N | Missense Mutation (SNP) | VAF 71/191 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs754871314, COSV56977587; called by muse, mutect2, varscan2
- ADAMTS17 | c.3265C>T p.R1089C | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.446); catalogued as rs765090779, COSV51472944; called by muse, mutect2, varscan2
- ADAMTS18 | c.3300G>T p.K1100N | Missense Mutation (SNP) | VAF 92/253 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.628); catalogued as COSV51398577, COSV51407276; called by muse, mutect2
- ADAMTS18 | c.1342G>A p.G448R | Missense Mutation (SNP) | VAF 86/224 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1018687209, COSV51398590; called by muse, mutect2, varscan2
- ADAMTS18 | c.642C>A p.Y214* | Nonsense Mutation (SNP) | VAF 56/140 reads (40%) | catalogued as COSV51398598, COSV51403695; called by muse, mutect2, varscan2
- ADAMTS19 | c.3470C>T p.T1157I | Missense Mutation (SNP) | VAF 130/360 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1421275401, COSV50731851, COSV50749008; called by muse, mutect2, varscan2
- ADAMTS20 | c.2420G>T p.R807I | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67125988; called by muse, mutect2, varscan2
- ADAMTS20 | c.1408G>T p.E470* | Nonsense Mutation (SNP) | VAF 33/116 reads (28%) | catalogued as COSV67125989; called by muse, mutect2, varscan2
- ADAMTS3 | c.2282G>T p.G761V | Missense Mutation (SNP) | VAF 228/604 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104378891, COSV54384367; called by muse, mutect2, varscan2
- ADAMTS4 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as rs546291574, COSV63487258; called by muse, mutect2, varscan2
- ADAMTS6 | c.1979A>C p.N660T | Missense Mutation (SNP) | VAF 43/134 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.12); catalogued as COSV66856630; called by muse, mutect2, varscan2
- ADAMTS7 | c.1706C>T p.T569M | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.083); catalogued as rs199628498; called by muse, mutect2, varscan2
- ADAMTS9 | c.3230T>C p.V1077A | Missense Mutation (SNP) | VAF 50/140 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.129); catalogued as COSV55774758; called by muse, mutect2, varscan2
- ADAMTS9 | c.2530C>T p.R844C | Missense Mutation (SNP) | VAF 85/200 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs759664813, COSV55774765; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2156C>T p.T719M | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs747836852, COSV65888191; called by muse, mutect2, varscan2
- ADAMTSL3 | c.4937C>A p.S1646Y | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV54435840, COSV54468085; called by muse, mutect2, varscan2
- ADCY10 | c.3649C>T p.R1217C | Missense Mutation (SNP) | VAF 64/170 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); catalogued as rs754372156, COSV63238479; called by muse, mutect2, varscan2
- ADCY2 | c.2228G>A p.S743N | Missense Mutation (SNP) | VAF 69/170 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as COSV57858494, COSV57858552; called by muse, mutect2, varscan2
- ADCY4 | c.2515C>T p.R839W | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs937602360, COSV60251848; called by muse, mutect2, varscan2
- ADCY4 | c.1932G>T p.K644N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as COSV60251859; called by muse, mutect2
- ADCY7 | c.965G>A p.R322Q | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1202891173, COSV54264517; called by muse, mutect2
- ADCY8 | c.522C>A p.F174L | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.037); catalogued as COSV53895941, COSV53903391; called by muse, mutect2
- ADCYAP1 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV52485710; called by muse, mutect2, varscan2
- ADGRA3 | c.3721G>A p.D1241N | Missense Mutation (SNP) | VAF 132/348 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.734); catalogued as rs756895556, COSV51560278; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRB3 | c.1814T>C p.L605S | Missense Mutation (SNP) | VAF 250/689 reads (36%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.99); catalogued as COSV65382152; called by muse, mutect2, varscan2
- ADGRD1 | c.89C>A p.S30* | Nonsense Mutation (SNP) | VAF 26/83 reads (31%) | catalogued as COSV55438665; called by muse, mutect2, varscan2
- ADGRE3 | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.241); catalogued as COSV53728256; called by muse, mutect2, varscan2
- ADGRE3 | c.577+2T>G p.X193_splice | Splice Site (SNP) | VAF 26/73 reads (36%) | catalogued as COSV53728260; called by muse, varscan2
- ADGRE3 | c.493C>A p.L165I | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.831); catalogued as COSV53728267, COSV99506430; called by muse, varscan2
- ADGRE5 | c.400G>A p.V134I | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs372889912; called by muse, mutect2, varscan2
- ADGRF2 | c.898G>T p.D300Y (on ENST00000296862 / NM_001368115.2; = p.D232Y on NM_153839.7) | Missense Mutation (SNP) | VAF 121/289 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); catalogued as COSV57286377, COSV57287603; called by muse, mutect2, varscan2
- ADGRG5 | c.1491C>A p.F497L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as COSV61082555; called by muse, mutect2, varscan2
- ADGRG6 | c.29G>A p.S10N | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); catalogued as rs1288909399, COSV51586186; called by muse, mutect2, varscan2
- ADGRG7 | c.2083G>T p.D695Y | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56293535; called by muse, mutect2, varscan2
- ADGRG7 | c.2350G>A p.E784K | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.054); catalogued as rs909433668, COSV56293550; called by muse, mutect2, varscan2
- ADGRL2 | c.1402T>C p.F468L | Missense Mutation (SNP) | VAF 82/202 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.314); catalogued as COSV54651461; called by muse, mutect2, varscan2
- ADGRL2 | c.4177G>A p.D1393N (on ENST00000370717 / NM_001366005.1; = p.D1337N on NM_012302.4) | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.191); catalogued as COSV54651510; called by muse, mutect2, varscan2
- ADGRL3 | c.2156T>G p.L719W (on ENST00000506720 / NM_001322402.2; = p.L651W on NM_015236.6) | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV72229223; called by muse, mutect2, varscan2
- ADGRL3 | c.3752G>A p.R1251Q (on ENST00000506720 / NM_001322402.2; = p.R1183Q on NM_015236.6) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1189094336, COSV72229226; called by muse, mutect2, varscan2
- ADGRL4 | c.752C>T p.T251M | Missense Mutation (SNP) | VAF 155/346 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as rs369699141; called by muse, mutect2, varscan2
- ADGRV1 | c.5944dup p.S1982Ffs*2 | Frame Shift Ins (INS) | VAF 35/116 reads (30%) | catalogued as rs1554081619; called by mutect2, pindel, varscan2
- ADGRV1 | c.12424C>T p.R4142W | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as rs534226753, COSV67978187; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRV1 | c.17083C>A p.L5695I | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67978194; called by muse, mutect2, varscan2
- ADH6 | c.441C>A p.F147L | Missense Mutation (SNP) | VAF 87/246 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52954910, COSV52956812; called by muse, mutect2, varscan2
- ADH6 | c.257A>C p.K86T | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV52954921; called by muse, mutect2, varscan2
- ADH7 | c.146T>G p.V49G | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52919619; called by muse, mutect2, varscan2
- ADK | c.564del p.T190Qfs*8 (on ENST00000286621; = p.T173Qfs*8 on NM_001123.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 75/242 reads (31%) | catalogued as rs771117099; called by mutect2, pindel, varscan2
- ADORA1 | c.555C>A p.F185L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV55141209; called by muse, mutect2, varscan2
- ADORA1 | c.800G>T p.S267I | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV55141213; called by muse, mutect2, varscan2
- ADPRM | c.822C>A p.F274L | Missense Mutation (SNP) | VAF 71/205 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.649); catalogued as COSV59378924; called by muse, mutect2, varscan2
- ADRA1A | c.929T>C p.I310T | Missense Mutation (SNP) | VAF 140/388 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV52356660; called by muse, varscan2
- ADSL | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs775646855, COSV53406568; called by muse, mutect2, varscan2
- ADTRP | c.139A>C p.T47P | Missense Mutation (SNP) | VAF 174/467 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57641711; called by muse, mutect2, varscan2
- AFAP1 | c.915G>T p.K305N | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as COSV61793157; called by muse, mutect2, varscan2
- AFAP1L1 | c.1111C>A p.H371N | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV57043742; called by muse, mutect2, varscan2
- AFF2 | c.3644C>A p.S1215Y | Missense Mutation (SNP) | VAF 98/150 reads (65%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.979); catalogued as COSV53975993; called by muse, mutect2, varscan2
- AFF3 | c.2015C>T p.S672F | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57839877; called by muse, mutect2, varscan2
- AFG1L | c.1207C>T p.R403C | Missense Mutation (SNP) | VAF 54/136 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs185227588, COSV64554670; called by muse, mutect2, varscan2
- AFTPH | c.340G>T p.E114* | Nonsense Mutation (SNP) | VAF 56/135 reads (41%) | catalogued as COSV53215752; called by muse, mutect2, varscan2
- AGBL2 | c.226C>T p.L76F | Missense Mutation (SNP) | VAF 83/250 reads (33%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as COSV54089922; called by muse, mutect2, varscan2
- AGFG1 | c.557G>A p.R186H | Missense Mutation (SNP) | VAF 138/379 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.715); catalogued as rs142029380; called by muse, mutect2, varscan2
- AGL | c.2089G>A p.G697S | Missense Mutation (SNP) | VAF 123/290 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771211030, COSV54047858; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AGMO | c.946G>T p.E316* | Nonsense Mutation (SNP) | VAF 58/149 reads (39%) | catalogued as COSV61105489, COSV61123901; called by muse, mutect2, varscan2
- AGMO | c.578A>C p.N193T | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV61105493; called by muse, mutect2, varscan2
- AGO1 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs748561732, COSV64594648; called by muse, mutect2, varscan2
- AGPS | c.990G>T p.E330D | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.562); catalogued as COSV51560805; called by muse, mutect2, varscan2
- AGTR1 | c.1027G>T p.D343Y | Missense Mutation (SNP) | VAF 53/153 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.385); catalogued as COSV62557251; called by muse, mutect2, varscan2
- AGXT2 | c.1349G>A p.R450Q | Missense Mutation (SNP) | VAF 72/201 reads (36%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV51483789; called by muse, mutect2, varscan2
- AGXT2 | c.605C>A p.P202H | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV51483798; called by muse, mutect2, varscan2
- AHCTF1 | c.5696T>G p.V1899G (on ENST00000366508; = p.V1873G on NM_015446.5) | Missense Mutation (SNP) | VAF 90/241 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV58245662; called by muse, mutect2, varscan2
- AHCY | c.1094A>G p.Q365R | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.829); catalogued as COSV54152406; called by muse, mutect2, varscan2
- AHCYL2 | c.558C>A p.F186L | Missense Mutation (SNP) | VAF 71/196 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV61485003; called by muse, mutect2, varscan2
- AHNAK | c.12325G>T p.E4109* | Nonsense Mutation (SNP) | VAF 88/256 reads (34%) | catalogued as COSV57203346; called by muse, mutect2, varscan2
- AHNAK | c.10567G>A p.E3523K | Missense Mutation (SNP) | VAF 62/184 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.291); catalogued as COSV57203356; called by muse, mutect2, varscan2
- AHNAK | c.6703C>A p.H2235N | Missense Mutation (SNP) | VAF 124/363 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.295); catalogued as COSV57202894; called by muse, mutect2, varscan2
- AHNAK2 | c.11398G>T p.D3800Y | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV60907334; called by muse, mutect2
- AHNAK2 | c.10651G>A p.G3551S | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.053); catalogued as rs199591478; called by muse, mutect2, varscan2
- AHNAK2 | c.4097C>A p.S1366Y | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV60932360; called by muse, mutect2, varscan2
- AHNAK2 | c.3087G>T p.E1029D | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV60907371; called by muse, mutect2, varscan2
- AHR | c.1505C>T p.P502L | Missense Mutation (SNP) | VAF 91/246 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.199); catalogued as rs533269895, COSV54121537, COSV99619757; called by muse, mutect2, varscan2
- AICDA | c.538C>A p.L180I | Missense Mutation (SNP) | VAF 139/418 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57563422, COSV57566722; called by muse, mutect2, varscan2
- AIG1 | c.178A>G p.T60A | Missense Mutation (SNP) | VAF 139/364 reads (38%) | SIFT tolerated (0.74); PolyPhen benign (0.088); catalogued as COSV51621934; called by muse, varscan2
- AIM2 | c.550G>T p.E184* | Nonsense Mutation (SNP) | VAF 67/215 reads (31%) | catalogued as COSV63698147; called by muse, mutect2, varscan2
- AIPL1 | c.973A>G p.N325D | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as COSV51505820; called by muse, mutect2, varscan2
- AJAP1 | c.857T>C p.I286T | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100981607, COSV65448818; called by muse, mutect2, varscan2
- AJAP1 | c.1091C>A p.S364Y | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.568); catalogued as COSV65448822; called by muse, mutect2, varscan2
- AK3 | c.359T>G p.V120G | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV63346836; called by muse, mutect2, varscan2
- AK5 | c.1262G>T p.R421I (on ENST00000354567 / NM_174858.3; = p.R395I on NM_012093.4) | Missense Mutation (SNP) | VAF 80/239 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV60967389; called by muse, mutect2, varscan2
- AK7 | c.531T>G p.D177E | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.299); catalogued as COSV50869187; called by muse, mutect2, varscan2
- AKAP11 | c.4942G>A p.A1648T | Missense Mutation (SNP) | VAF 83/226 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV50292502; called by muse, mutect2, varscan2
- AKAP12 | c.2570G>T p.R857M | Missense Mutation (SNP) | VAF 57/189 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.292); catalogued as COSV53570034; called by muse, mutect2, varscan2
- AKAP12 | c.3271G>A p.D1091N | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.115); catalogued as COSV53570050; called by muse, mutect2, varscan2
- AKAP13 | c.5127C>A p.F1709L (on ENST00000394518 / NM_007200.5; = p.F1713L on NM_006738.6) | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV63448017, COSV63455453; called by muse, varscan2
- AKAP3 | c.1471G>T p.D491Y | Missense Mutation (SNP) | VAF 89/232 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV57413597; called by muse, mutect2, varscan2
- AKAP3 | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 120/322 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs749375251, COSV57413608, COSV99962219; called by muse, mutect2, varscan2
- AKAP5 | c.1273C>A p.L425I | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.494); catalogued as COSV57742051; called by muse, mutect2, varscan2
- AKAP6 | c.2585G>A p.R862Q | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs761876269, COSV55204580; called by muse, mutect2, varscan2
- AKAP7 | c.469G>T p.E157* | Nonsense Mutation (SNP) | VAF 114/308 reads (37%) | catalogued as COSV63504692; called by muse, mutect2, varscan2
- AKAP9 | c.4670A>C p.K1557T | Missense Mutation (SNP) | VAF 64/191 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.31); catalogued as COSV62338380; called by muse, mutect2, varscan2
- AKAP9 | c.5347C>T p.R1783C (on ENST00000359028; = p.R1751C on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/213 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.318); catalogued as rs144269839; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AKAP9 | c.8122G>T p.E2708* (on ENST00000359028; = p.E2684* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 72/190 reads (38%) | catalogued as COSV62338404; called by muse, varscan2
- AKAP9 | c.9174C>A p.F3058L (on ENST00000359028; = p.F3034L on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 136/375 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.628); catalogued as COSV62338420; called by muse, mutect2, varscan2
- AKIRIN2 | c.507A>C p.E169D | Missense Mutation (SNP) | VAF 65/204 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV57635911; called by muse, mutect2, varscan2
- AKR1B15 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV71150986; called by muse, mutect2, varscan2
- AKR1C2 | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as rs782503043; called by muse, mutect2, varscan2
- AKT3 | c.1355-1G>T p.X452_splice | Splice Site (SNP) | VAF 14/61 reads (23%) | catalogued as COSV55607126; called by muse, mutect2, varscan2
- AL121899.2 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs146616453; called by muse, mutect2, varscan2
- AL121899.2 | c.2125G>A p.D709N | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs767808303, COSV67349602; called by muse, mutect2, varscan2
- AL136295.1 | c.2041T>G p.F681V | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.918); catalogued as COSV55777850; called by muse, mutect2, varscan2
- AL592490.1 | c.2249C>A p.S750Y | Missense Mutation (SNP) | VAF 66/206 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1400830598, COSV69424427; called by muse, mutect2, varscan2
- AL592490.1 | c.529C>A p.L177I | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV69424436; called by muse, mutect2, varscan2
- AL645922.1 | c.1754G>A p.S585N | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as COSV54959158; called by muse, mutect2, varscan2
- ALAS1 | c.919C>T p.L307F | Missense Mutation (SNP) | VAF 57/131 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59626767; called by muse, mutect2, varscan2
- ALAS1 | c.1169C>T p.A390V | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs773336919, COSV59626776; called by muse, mutect2, varscan2
- ALDH18A1 | c.2347C>A p.L783I | Missense Mutation (SNP) | VAF 94/258 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV64662039; called by muse, mutect2, varscan2
- ALDH1A1 | c.1145T>C p.V382A | Missense Mutation (SNP) | VAF 80/211 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as COSV52789047; called by muse, mutect2, varscan2
- ALDH1A2 | c.264C>A p.F88L | Missense Mutation (SNP) | VAF 170/495 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51078081; called by muse, mutect2, varscan2
- ALDH1B1 | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV66619191; called by muse, mutect2, varscan2
- ALDH1B1 | c.716C>T p.T239M | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs779633928, COSV66619196; called by muse, mutect2, varscan2
- ALDH1B1 | c.1130G>A p.G377D | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as COSV66619204, COSV66620431; called by muse, mutect2, varscan2
- ALDH1L1 | c.1862G>A p.G621D | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56410518; called by muse, mutect2, varscan2
- ALDH1L1 | c.835C>A p.L279I | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.074); catalogued as COSV56416224; called by muse, mutect2
- ALDH3A2 | c.475C>A p.L159I | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); catalogued as COSV51565516; called by muse, varscan2
- ALDH9A1 | c.1245G>T p.E415D | Missense Mutation (SNP) | VAF 66/226 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV61338943; called by muse, mutect2, varscan2
- ALG10B | c.700C>A p.L234I | Missense Mutation (SNP) | VAF 132/373 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as rs1218991576, COSV100439817, COSV58142197; called by muse, mutect2, varscan2
- ALG11 | c.623C>A p.S208Y | Missense Mutation (SNP) | VAF 80/201 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as CD122081, COSV73000556; called by muse, mutect2, varscan2
- ALG11 | c.926T>G p.F309C | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV73000557; called by muse, mutect2, varscan2
- ALG2 | c.905C>A p.S302Y | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53058670; called by muse, mutect2, varscan2
- ALG6 | c.823G>T p.V275L | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.307); catalogued as rs1271387707; called by muse, mutect2, varscan2
- ALG8 | c.1535T>G p.V512G | Missense Mutation (SNP) | VAF 80/190 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.112); catalogued as COSV104409384, COSV55199116; called by muse, mutect2, varscan2
- ALMS1 | c.6196G>T p.D2066Y | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.837); catalogued as COSV52502350, COSV52519674; called by muse, mutect2
- ALMS1 | c.8576C>T p.S2859L | Missense Mutation (SNP) | VAF 162/426 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.021); catalogued as rs538382027, CM156242, COSV52502380; called by muse, mutect2, varscan2
- ALMS1 | c.10574A>G p.H3525R | Missense Mutation (SNP) | VAF 139/399 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.568); catalogued as COSV52502395; called by muse, mutect2, varscan2
- ALMS1 | c.11329G>A p.E3777K | Missense Mutation (SNP) | VAF 189/501 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs565098671, COSV52502407; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALOX5 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.178); catalogued as rs560031203, COSV65550928; called by muse, mutect2, varscan2
- ALOX5AP | c.75C>A p.F25L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.884); catalogued as rs776630925, COSV100996268, COSV66857642; called by muse, mutect2
- ALPK1 | c.2266G>A p.D756N | Missense Mutation (SNP) | VAF 72/215 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs768671654, COSV51581543; called by muse, mutect2, varscan2
- ALPK2 | c.5042C>T p.A1681V | Missense Mutation (SNP) | VAF 60/142 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs758281980, COSV64490174; called by muse, mutect2, varscan2
- ALPL | c.1526G>A p.G509D | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.42); PolyPhen benign (0.031); catalogued as rs79250591, COSV66375930; called by muse, mutect2, varscan2
- ALS2 | c.4125C>A p.A1375= | Splice Region (SNP) | VAF 82/178 reads (46%) | catalogued as COSV51883902; called by muse, mutect2, varscan2
- ALS2 | c.3618A>C p.K1206N | Missense Mutation (SNP) | VAF 156/382 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.728); catalogued as COSV51883916; called by muse, mutect2, varscan2
- AMER1 | c.1405G>T p.E469* | Nonsense Mutation (SNP) | VAF 36/63 reads (57%) | catalogued as COSV57654627; called by muse, mutect2, varscan2
- AMOTL1 | c.1654G>T p.E552* | Nonsense Mutation (SNP) | VAF 4/15 reads (27%) | catalogued as COSV58564990; called by muse, mutect2, varscan2
- AMPH | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57732577; called by muse, mutect2, varscan2
- AMY2A | c.746T>G p.V249G | Missense Mutation (SNP) | VAF 107/308 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70214250; called by muse, mutect2, varscan2
- ANAPC10 | c.511C>A p.P171T | Missense Mutation (SNP) | VAF 84/278 reads (30%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.636); catalogued as COSV58738360; called by muse, varscan2
- ANAPC10 | c.442G>A p.G148R | Missense Mutation (SNP) | VAF 87/260 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100518763, COSV58738370; called by muse, varscan2
- ANGPTL2 | c.1264G>T p.D422Y | Missense Mutation (SNP) | VAF 82/225 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52215716; called by muse, mutect2, varscan2
- ANK1 | c.4613A>G p.D1538G | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.066); catalogued as COSV55872508; called by muse, mutect2, varscan2
- ANK2 | c.7633G>T p.E2545* | Nonsense Mutation (SNP) | VAF 174/482 reads (36%) | catalogued as COSV52145214; called by muse, mutect2, varscan2
- ANK2 | c.10702C>T p.R3568W | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs72556376; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK2 | c.11259C>A p.F3753L | Missense Mutation (SNP) | VAF 80/210 reads (38%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.05); catalogued as COSV52145235; called by muse, varscan2
- ANK2 | c.11786A>G p.N3929S | Missense Mutation (SNP) | VAF 86/242 reads (36%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.001); catalogued as COSV52145245; called by muse, mutect2, varscan2
- ANK3 | c.12998C>A p.S4333Y (on ENST00000280772 / NM_001320874.2; = p.S957Y on NM_001149.3) | Missense Mutation (SNP) | VAF 160/437 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.163); catalogued as COSV55043606, COSV55077554; called by muse, mutect2, varscan2
- ANK3 | c.11539C>A p.L3847I | Missense Mutation (SNP) | VAF 261/692 reads (38%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.015); catalogued as COSV55043620; called by muse, mutect2, varscan2
- ANKFY1 | c.2883T>G p.N961K (on ENST00000341657 / NM_001330063.2; = p.N962K on NM_016376.5) | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); catalogued as COSV58914440; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.847G>T p.G283C | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51840249; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4100G>A p.R1367H | Missense Mutation (SNP) | VAF 51/152 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs757899078, COSV51840263; called by muse, mutect2, varscan2
- ANKLE2 | c.1227G>T p.K409N | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV61707749; called by muse, varscan2
- ANKMY2 | c.820T>G p.F274V | Missense Mutation (SNP) | VAF 40/109 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61010940; called by muse, mutect2, varscan2
- ANKRD1 | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65467117, COSV65468105; called by muse, mutect2, varscan2
- ANKRD1 | c.96G>T p.E32D | Missense Mutation (SNP) | VAF 141/424 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV63310876; called by muse, mutect2, varscan2
- ANKRD12 | c.3916G>T p.E1306* | Nonsense Mutation (SNP) | VAF 178/479 reads (37%) | catalogued as COSV50819073; called by muse, mutect2, varscan2
- ANKRD26 | c.3392C>T p.S1131F | Missense Mutation (SNP) | VAF 201/544 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65773911; called by muse, varscan2
- ANKRD26 | c.3169G>T p.D1057Y | Missense Mutation (SNP) | VAF 170/472 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs969387790, COSV65773914; called by muse, varscan2
- ANKRD28 | c.2994T>G p.N998K | Missense Mutation (SNP) | VAF 80/212 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.021); catalogued as COSV67516829; called by muse, mutect2, varscan2
- ANKRD30A | c.389C>T p.A130V (on ENST00000611781; = p.A74V on NM_052997.2) | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV64603588; called by muse, mutect2, varscan2
- ANKRD30A | c.1458T>C p.S486= (on ENST00000611781; = p.S430= on NM_052997.2) | Splice Region (SNP) | VAF 15/62 reads (24%) | catalogued as COSV64603595; called by muse, mutect2, varscan2
- ANKRD34A | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV60160244; called by muse, mutect2, varscan2
- ANKRD35 | c.1862G>T p.R621I | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62909490; called by muse, mutect2, varscan2
- ANKRD35 | c.1544G>T p.R515I | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV62909483; called by muse, mutect2, varscan2
- ANKRD42 | c.788T>G p.I263S | Missense Mutation (SNP) | VAF 159/419 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV52614297; called by muse, mutect2, varscan2
- ANKRD49 | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs1361548385, COSV57059778; called by muse, mutect2, varscan2
- ANKRD50 | c.2182G>A p.A728T | Missense Mutation (SNP) | VAF 110/233 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.073); catalogued as rs377077898; called by muse, mutect2, varscan2
- ANKRD52 | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57282053; called by muse, mutect2, varscan2
- ANKRD52 | c.617G>A p.G206D | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as rs1320907610, COSV57282081; called by muse, mutect2, varscan2
- ANKRD55 | c.1249C>A p.L417I | Missense Mutation (SNP) | VAF 83/183 reads (45%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.012); catalogued as COSV61944174; called by muse, mutect2, varscan2
- ANKRD7 | c.428A>C p.K143T | Missense Mutation (SNP) | VAF 64/147 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV54553773; called by muse, mutect2, varscan2
- ANKRD7 | c.574A>C p.R192= | Splice Region (SNP) | VAF 31/88 reads (35%) | catalogued as COSV54553786; called by muse, mutect2, varscan2
- ANKS1B | c.1795G>T p.E599* | Nonsense Mutation (SNP) | VAF 143/404 reads (35%) | catalogued as COSV61334452; called by muse, varscan2
- ANKS1B | c.1086G>T p.K362N | Missense Mutation (SNP) | VAF 41/119 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV61334459; called by muse, mutect2, varscan2
- ANO10 | c.1466G>A p.G489E | Missense Mutation (SNP) | VAF 118/320 reads (37%) | SIFT tolerated (0.68); PolyPhen benign (0.012); catalogued as COSV52728301; called by muse, mutect2, varscan2
- ANO3 | c.2153A>G p.N718S | Missense Mutation (SNP) | VAF 71/195 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56779976; called by muse, mutect2, varscan2
- ANO5 | c.75C>A p.F25L | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV61081900; called by muse, mutect2, varscan2
- ANO5 | c.1335G>T p.E445D | Missense Mutation (SNP) | VAF 57/128 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV100201535, COSV61081911; called by muse, mutect2, varscan2
- ANO5 | c.2200C>A p.L734I | Missense Mutation (SNP) | VAF 130/330 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs886042760, COSV61081922; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANO5 | c.2591G>T p.R864I | Missense Mutation (SNP) | VAF 78/199 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV61081929; called by muse, mutect2, varscan2
- ANOS1 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as rs199725550, COSV52915809; called by muse, mutect2, varscan2
- ANPEP | c.2434G>A p.A812T | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as rs759355791, COSV55589093; called by muse, mutect2, varscan2
- ANTXR2 | c.1295G>A p.R432Q | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as rs767242762, COSV56312614; called by muse, varscan2
- ANXA11 | c.874G>T p.E292* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as COSV55414990; called by muse, mutect2, varscan2
- ANXA4 | c.655C>G p.Q219E | Missense Mutation (SNP) | VAF 85/243 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV67848252; called by muse, mutect2, varscan2
- ANXA6 | c.1307C>T p.P436L | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs34326317; called by muse, varscan2
- ANXA7 | c.991C>T p.R331C (on ENST00000372919 / NM_001320880.2; = p.R309C on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 275/710 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770697765, COSV65822874; called by muse, mutect2, varscan2
- AP000812.4 | c.23G>T p.R8I | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV53825194; called by muse, mutect2, varscan2
- AP1AR | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 16/47 reads (34%) | catalogued as COSV56768456; called by muse, mutect2, varscan2
- AP2B1 | c.869C>A p.T290N | Missense Mutation (SNP) | VAF 175/483 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51996898; called by muse, mutect2, varscan2
- AP3B1 | c.942+1G>A p.X314_splice | Splice Site (SNP) | VAF 63/156 reads (40%) | catalogued as COSV54876207; called by muse, mutect2, varscan2
- AP3M1 | c.860C>A p.S287Y | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV62330646; called by muse, mutect2, varscan2
- AP4B1 | c.1397C>T p.S466L | Missense Mutation (SNP) | VAF 108/247 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.254); catalogued as rs767747484, COSV56723146; called by muse, mutect2, varscan2
- AP4E1 | c.559A>T p.K187* | Nonsense Mutation (SNP) | VAF 33/92 reads (36%) | catalogued as COSV55914940; called by muse, mutect2, varscan2
- AP4E1 | c.1029A>C p.K343N | Missense Mutation (SNP) | VAF 57/166 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.085); catalogued as COSV55914948; called by muse, mutect2, varscan2
- APAF1 | c.796G>T p.D266Y (on ENST00000551964 / NM_181861.2; = p.D255Y on NM_001160.3) | Missense Mutation (SNP) | VAF 49/165 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59661498; called by muse, mutect2, varscan2
- APAF1 | c.1301G>A p.R434H (on ENST00000551964 / NM_181861.2; = p.R423H on NM_001160.3) | Missense Mutation (SNP) | VAF 75/217 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs201872620, COSV59661508; called by muse, mutect2, varscan2
- APC | c.5C>A p.A2D | Missense Mutation (SNP) | VAF 69/140 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57323956; called by muse, mutect2, varscan2
- APC | c.1592C>T p.A531V | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57323970; called by muse, mutect2, varscan2
- APC | c.7286C>T p.S2429F | Missense Mutation (SNP) | VAF 93/247 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57324028; called by muse, mutect2, varscan2
- APCDD1L | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs1345245430, COSV64485311; called by muse, mutect2, varscan2
- APEH | c.2095C>T p.L699F | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as rs1273489482, COSV56531965; called by muse, mutect2, varscan2
- APLF | c.1237G>T p.D413Y | Missense Mutation (SNP) | VAF 12/317 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV58142758; called by muse, mutect2
- APLP2 | c.1508A>C p.D503A | Missense Mutation (SNP) | VAF 61/163 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53838766; called by muse, mutect2, varscan2
- APOA4 | c.505C>T p.R169W | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.302); catalogued as rs142295954, COSV63360637; called by muse, mutect2, varscan2
- APOB | c.11104C>A p.L3702I | Missense Mutation (SNP) | VAF 77/195 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.881); catalogued as COSV51922619; called by muse, mutect2, varscan2
- APOB | c.9346G>T p.G3116* | Nonsense Mutation (SNP) | VAF 114/292 reads (39%) | catalogued as COSV51922643; called by muse, varscan2
- APOB | c.6970C>A p.L2324I | Missense Mutation (SNP) | VAF 104/284 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as COSV51922652; called by muse, mutect2, varscan2
- APOB | c.4481C>T p.S1494L | Missense Mutation (SNP) | VAF 91/236 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs1020402380, COSV51922665; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APOB | c.1865C>A p.S622Y | Missense Mutation (SNP) | VAF 79/196 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as COSV51922687; called by muse, mutect2, varscan2
- APOB | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.369); catalogued as rs780841518, COSV51922701; called by muse, mutect2, varscan2
- APOBEC1 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV57548150; called by muse, mutect2, varscan2
- APOBEC4 | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 99/246 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as rs370218327, COSV58016833; called by muse, mutect2, varscan2
- APOL5 | c.22A>C p.N8H | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.432); catalogued as COSV50766346; called by muse, mutect2, varscan2
- APOLD1 | c.609C>A p.F203L (on ENST00000326765 / NM_001130415.2; = p.F172L on NM_030817.3) | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.089); catalogued as COSV58731825; called by muse, mutect2, varscan2
- AQP10 | c.420G>T p.K140N | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV61474362; called by muse, mutect2, varscan2
- AQP10 | c.529A>G p.I177V | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.191); catalogued as COSV61474366; called by muse, mutect2
- AQP9 | c.151C>T p.R51* | Nonsense Mutation (SNP) | VAF 129/365 reads (35%) | catalogued as rs370192849, COSV54967386; called by muse, mutect2, varscan2
- AQP9 | c.740C>A p.P247H | Missense Mutation (SNP) | VAF 81/256 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54967394; called by muse, mutect2, varscan2
- AQR | c.2714G>T p.R905I | Missense Mutation (SNP) | VAF 93/262 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50030296; called by muse, mutect2, varscan2
- AQR | c.1930A>C p.N644H | Missense Mutation (SNP) | VAF 83/215 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV50029516; called by muse, mutect2, varscan2
- ARAP2 | c.2431G>T p.E811* | Nonsense Mutation (SNP) | VAF 27/59 reads (46%) | catalogued as COSV58282364; called by muse, mutect2, varscan2
- ARF6 | c.91T>C p.Y31H | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV53597167; called by muse, mutect2, varscan2
- ARFGAP3 | c.1481C>T p.S494L | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54310421; called by muse, mutect2, varscan2
- ARFGEF1 | c.1585G>T p.E529* | Nonsense Mutation (SNP) | VAF 109/289 reads (38%) | catalogued as COSV51602242; called by muse, mutect2, varscan2
- ARG2 | c.661G>T p.D221Y | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs746928269, COSV53619040; called by muse, mutect2, varscan2
- ARGFX | c.591G>T p.E197D | Missense Mutation (SNP) | VAF 161/401 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV100544072, COSV57681552; called by muse, mutect2, varscan2
- ARHGAP10 | c.353A>C p.K118T | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV60594740; called by muse, mutect2, varscan2
- ARHGAP19 | c.665A>G p.D222G | Missense Mutation (SNP) | VAF 65/191 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV57391349; called by muse, mutect2, varscan2
- ARHGAP20 | c.1635G>T p.E545D | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.056); catalogued as COSV52806386; called by muse, mutect2, varscan2
- ARHGAP21 | c.3643G>T p.D1215Y | Missense Mutation (SNP) | VAF 47/122 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57601918; called by muse, mutect2, varscan2
- ARHGAP25 | c.1410C>A p.F470L (on ENST00000409202 / NM_001007231.3; = p.F462L on NM_014882.3) | Missense Mutation (SNP) | VAF 72/174 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0.027); catalogued as COSV54909752; called by muse, varscan2
- ARHGAP28 | c.1215T>G p.F405L (on ENST00000383472 / NM_001366230.1; = p.F246L on NM_001010000.3) | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV51631297; called by muse, mutect2, varscan2
- ARHGAP29 | c.2876C>T p.A959V | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as rs377417799; called by muse, mutect2, varscan2
- ARHGAP29 | c.1192G>T p.E398* | Nonsense Mutation (SNP) | VAF 36/108 reads (33%) | catalogued as COSV53108027; called by muse, mutect2, varscan2
- ARHGAP30 | c.588G>T p.E196D | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV63514787; called by muse, mutect2
- ARHGAP31 | c.1994C>A p.S665Y | Missense Mutation (SNP) | VAF 196/591 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV51788945; called by muse, mutect2, varscan2
- ARHGAP32 | c.569G>A p.R190Q | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV59843113; called by muse, mutect2, varscan2
- ARHGAP33 | c.1477C>T p.R493W | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs143998454; called by muse, mutect2, varscan2
- ARHGAP35 | c.2348G>A p.R783Q | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV68329135; called by muse, mutect2, varscan2
- ARHGAP35 | c.3433C>T p.R1145* | Nonsense Mutation (SNP) | VAF 19/53 reads (36%) | catalogued as COSV68329138; called by muse, mutect2, varscan2
- ARHGEF12 | c.1547G>A p.R516Q | Missense Mutation (SNP) | VAF 90/221 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs1032127134, COSV63102469; called by muse, mutect2, varscan2
- ARHGEF12 | c.1749G>T p.K583N | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as COSV63102475; called by muse, varscan2
- ARHGEF12 | c.2173G>T p.E725* | Nonsense Mutation (SNP) | VAF 137/348 reads (39%) | catalogued as COSV100754939, COSV63102481; called by muse, mutect2, varscan2
- ARHGEF12 | c.3319G>A p.A1107T | Missense Mutation (SNP) | VAF 56/131 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1339463961, COSV63102485; called by muse, mutect2, varscan2
- ARHGEF15 | c.2201G>A p.R734H | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs775473270, COSV62724278; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGEF26 | c.2538G>T p.K846N | Missense Mutation (SNP) | VAF 71/179 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); catalogued as COSV62843723; called by muse, mutect2, varscan2
- ARHGEF28 | c.2032T>C p.S678P | Missense Mutation (SNP) | VAF 259/714 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); catalogued as COSV55247181; called by muse, mutect2, varscan2
- ARHGEF28 | c.3106G>T p.D1036Y | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs750588590, COSV55247202; called by muse, mutect2, varscan2
- ARHGEF28 | c.4090T>G p.F1364V | Missense Mutation (SNP) | VAF 72/219 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV55247215; called by muse, mutect2, varscan2
- ARHGEF28 | c.4289C>T p.A1430V | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs1443768629, COSV55254836; called by muse, mutect2
- ARHGEF3 | c.835A>C p.N279H | Missense Mutation (SNP) | VAF 97/229 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.81); catalogued as COSV56323337; called by muse, mutect2, varscan2
- ARHGEF37 | c.1540A>G p.T514A | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as COSV61367868; called by muse, mutect2, varscan2
- ARID1A | c.3667C>T p.R1223C | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1227227387, COSV61371570; called by muse, mutect2, varscan2
- ARID4A | c.677G>A p.R226K | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); catalogued as COSV62161928; called by muse, mutect2, varscan2
- ARID4A | c.1753C>T p.R585* | Nonsense Mutation (SNP) | VAF 70/162 reads (43%) | catalogued as COSV62161933; called by muse, mutect2, varscan2
- ARID5B | c.3085C>T p.R1029W | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54413908, COSV54422079; called by muse, mutect2, varscan2
- ARL1 | c.494G>A p.G165D | Missense Mutation (SNP) | VAF 63/177 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55369862; called by muse, mutect2, varscan2
- ARL8B | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs766948599, COSV56577028; called by muse, mutect2, varscan2
- ARMC12 | c.657G>T p.K219N (on ENST00000373866 / NM_001286574.2; = p.K246N on NM_145028.5) | Missense Mutation (SNP) | VAF 85/227 reads (37%) | SIFT tolerated (0.72); PolyPhen benign (0.015); catalogued as COSV55359123; called by muse, mutect2, varscan2
- ARMC3 | c.2455G>A p.E819K | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.86); catalogued as COSV53056896; called by muse, mutect2, varscan2
- ARMC4 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.636); catalogued as rs866196713, COSV59455677; called by muse, mutect2, varscan2
- ARMC8 | c.531G>A p.G177= (on ENST00000469044 / NM_001363941.2; = p.G163= on NM_014154.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 19/74 reads (26%) | catalogued as rs957793427, COSV61767598; called by muse, mutect2, varscan2
- ARMH3 | c.2055C>A p.F685L | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV53306271, COSV53307324, COSV53307859; called by muse, mutect2, varscan2
- ARMH4 | c.1370A>C p.D457A | Missense Mutation (SNP) | VAF 59/142 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as COSV50761520; called by muse, mutect2, varscan2
- ARNTL | c.741C>A p.F247L | Missense Mutation (SNP) | VAF 114/340 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100724735, COSV62985136; called by muse, varscan2
- ARNTL | c.813G>T p.K271N | Missense Mutation (SNP) | VAF 82/255 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100724846, COSV62985140; called by muse, varscan2
- ARNTL2 | c.1321G>T p.D441Y | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.736); catalogued as COSV53823278; called by muse, mutect2, varscan2
- ARPC2 | c.304C>A p.L102I | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT tolerated (0.27); PolyPhen benign (0.013); catalogued as COSV55283588; called by muse, mutect2, varscan2
- ARPP21 | c.2167A>C p.M723L | Missense Mutation (SNP) | VAF 48/133 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV51791906; called by muse, mutect2, varscan2
- ARSB | c.1435C>T p.R479W | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.478); catalogued as rs758641798, COSV53718888; called by muse, mutect2, varscan2
- ARSB | c.518A>G p.E173G | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.781); catalogued as COSV53718904; called by muse, mutect2, varscan2
- ART1 | c.108G>T p.E36D | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV51702823; called by muse, mutect2, varscan2
- ASAH1 | c.849G>T p.K283N | Missense Mutation (SNP) | VAF 91/235 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.726); catalogued as rs1352441199; called by muse, mutect2, varscan2
- ASAP2 | c.1252G>T p.E418* | Nonsense Mutation (SNP) | VAF 22/70 reads (31%) | catalogued as COSV55627197; called by muse, mutect2, varscan2
- ASB4 | c.1081G>T p.D361Y | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV57942806; called by muse, mutect2, varscan2
- ASB5 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.045); catalogued as COSV56668461, COSV56670474; called by muse, mutect2, varscan2
- ASH1L | c.3917G>A p.R1306Q | Missense Mutation (SNP) | VAF 155/452 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as rs758885213, COSV64205321; called by muse, mutect2, varscan2
- ASH1L | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 98/270 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.146); catalogued as rs867128307, COSV64205328; called by muse, varscan2
- ASIC2 | c.1348C>T p.L450F | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1337592623, COSV56755353; called by muse, mutect2, varscan2
- ASIC5 | c.659G>T p.R220I | Missense Mutation (SNP) | VAF 80/241 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV72232493; called by muse, mutect2, varscan2
- ASPA | c.311A>G p.D104G | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1321065570, COSV53979938; called by muse, mutect2, varscan2
- ASPHD1 | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.048); catalogued as rs150342901, COSV58097096; called by muse, mutect2, varscan2
- ASPHD1 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as COSV58097098; called by muse, mutect2, varscan2
- ASPM | c.9094G>A p.A3032T | Missense Mutation (SNP) | VAF 136/361 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.984); catalogued as rs1429482664, COSV54124352; called by muse, mutect2, varscan2
- ASPM | c.7896G>T p.Q2632H | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54124359; called by muse, mutect2, varscan2
- ASPM | c.3983G>T p.R1328I | Missense Mutation (SNP) | VAF 245/674 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV54124369; called by muse, mutect2, varscan2
- ASPRV1 | c.620T>C p.V207A | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as COSV57227343; called by muse, mutect2, varscan2
- ASTL | c.196G>T p.E66* | Nonsense Mutation (SNP) | VAF 8/18 reads (44%) | catalogued as COSV60903516; called by muse, mutect2, varscan2
- ASTN1 | c.1780C>T p.L594F | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as COSV56061200, COSV56070061; called by muse, mutect2, varscan2
- ASTN1 | c.255G>T p.E85D | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated, low confidence (0.58); PolyPhen probably damaging (0.971); catalogued as COSV56061207; called by muse, mutect2, varscan2
- ASTN2 | c.2693A>T p.Q898L (on ENST00000313400 / NM_001365069.1; = p.Q847L on NM_014010.5) | Missense Mutation (SNP) | VAF 61/160 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as COSV57749928; called by muse, mutect2, varscan2
- ASXL1 | c.124G>T p.G42* | Nonsense Mutation (SNP) | VAF 62/182 reads (34%) | catalogued as COSV60102942, COSV60105039; called by muse, varscan2
- ASXL3 | c.469C>A p.L157I | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); catalogued as COSV52456783; called by muse, mutect2, varscan2
- ASXL3 | c.1058T>C p.F353S | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52456793, COSV52457412; called by muse, mutect2, varscan2
- ATAD2B | c.3885C>A p.F1295L | Missense Mutation (SNP) | VAF 28/709 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53197908; called by muse, mutect2
- ATAD2B | c.670G>T p.E224* | Nonsense Mutation (SNP) | VAF 12/31 reads (39%) | catalogued as COSV53194985; called by muse, mutect2, varscan2
- ATAD5 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 57/162 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.02); catalogued as rs373509661, COSV58971918; called by muse, mutect2, varscan2
- ATAD5 | c.3098G>T p.R1033I | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1041463783, COSV58971929; called by muse, mutect2, varscan2
- ATCAY | c.252C>A p.F84L | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.64); PolyPhen benign (0.023); catalogued as COSV56654097, COSV56659076; called by muse, mutect2, varscan2
- ATCAY | c.809T>C p.I270T | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56654110; called by muse, mutect2, varscan2
- ATE1 | c.856G>T p.A286S | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.006); catalogued as COSV56433223; called by muse, mutect2, varscan2
- ATF7IP | c.1231A>G p.N411D | Missense Mutation (SNP) | VAF 66/189 reads (35%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV53766088; called by muse, mutect2, varscan2
- ATG10 | c.397C>A p.H133N | Missense Mutation (SNP) | VAF 127/391 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.565); catalogued as COSV56422412; called by muse, mutect2, varscan2
- ATG16L1 | c.1429C>T p.R477* (on ENST00000392017 / NM_030803.7; = p.R458* on NM_017974.4) | Nonsense Mutation (SNP) | VAF 66/176 reads (38%) | catalogued as COSV61464147, COSV61468342; called by muse, mutect2, varscan2
- ATG2B | c.3955A>G p.I1319V | Missense Mutation (SNP) | VAF 63/185 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55889374; called by muse, mutect2, varscan2
- ATL1 | c.437A>G p.D146G | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63295844; called by muse, mutect2, varscan2
- ATL2 | c.979C>A p.L327M | Missense Mutation (SNP) | VAF 94/300 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.903); catalogued as COSV60050329; called by muse, varscan2
- ATM | c.4996G>T p.E1666* | Nonsense Mutation (SNP) | VAF 29/92 reads (32%) | catalogued as COSV53725405, COSV53767865; called by muse, mutect2, varscan2
- ATM | c.6418T>G p.F2140V | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.176); catalogued as COSV53725417; called by muse, mutect2, varscan2
- ATM | c.7057C>A p.P2353T | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV53725426, COSV53785403; called by muse, mutect2, varscan2
- ATMIN | c.1226C>A p.S409Y | Missense Mutation (SNP) | VAF 86/201 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV55145089; called by muse, mutect2, varscan2
- ATOH1 | c.931T>G p.L311V | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.351); catalogued as COSV60037356; called by muse, mutect2, varscan2
- ATP10A | c.979G>A p.G327R | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs148331114; called by muse, mutect2, varscan2
- ATP10D | c.266G>T p.R89I | Missense Mutation (SNP) | VAF 67/175 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); catalogued as COSV56703617, COSV56706850; called by muse, mutect2, varscan2
- ATP10D | c.1756G>A p.D586N | Missense Mutation (SNP) | VAF 81/173 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs561130132, COSV56703624; called by muse, mutect2, varscan2
- ATP10D | c.2420C>T p.S807L | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.022); catalogued as rs145762869; called by muse, mutect2, varscan2
- ATP10D | c.2890G>T p.E964* | Nonsense Mutation (SNP) | VAF 31/73 reads (42%) | catalogued as COSV56703647; called by muse, mutect2, varscan2
- ATP11C | c.141A>C p.R47S | Missense Mutation (SNP) | VAF 84/141 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59559419; called by muse, mutect2, varscan2
- ATP12A | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs745443085, COSV54512186; called by muse, mutect2, varscan2
- ATP12A | c.2311G>A p.A771T | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.247); catalogued as rs750121465, COSV54512200; called by muse, mutect2, varscan2
- ATP13A4 | c.1483G>A p.G495S | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as rs748768301, COSV55065774; called by muse, mutect2, varscan2
- ATP13A4 | c.1394G>A p.G465D | Missense Mutation (SNP) | VAF 62/187 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as rs756991830, COSV55065788; called by muse, mutect2, varscan2
- ATP13A4 | c.51G>T p.E17D | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as COSV55065799; called by muse, mutect2, varscan2
- ATP13A5 | c.2316G>T p.K772N | Missense Mutation (SNP) | VAF 75/188 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.049); catalogued as COSV60865589; called by muse, mutect2, varscan2
- ATP1A2 | c.1056G>T p.K352N | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63402197; called by muse, mutect2, varscan2
- ATP1A3 | c.1450C>T p.P484S (on ENST00000545399 / NM_001256214.2; = p.P471S on NM_152296.5) | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV57484959; called by muse, mutect2, varscan2
- ATP1A4 | c.756C>A p.F252L | Missense Mutation (SNP) | VAF 79/222 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.24); catalogued as COSV100927640, COSV63625395; called by muse, mutect2, varscan2
- ATP1B1 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 54/146 reads (37%) | SIFT tolerated (0.17); PolyPhen probably damaging (1); catalogued as rs902788197, COSV63178819; called by muse, varscan2
- ATP23 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 86/286 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1479183882, COSV55685387; called by muse, mutect2, varscan2
- ATP23 | c.478G>T p.D160Y | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV55685396; called by muse, mutect2, varscan2
- ATP2A1 | c.153G>T p.E51D | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV63919898; called by muse, mutect2, varscan2
- ATP2B1 | c.1546A>G p.T516A | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.036); catalogued as COSV53803693; called by muse, mutect2, varscan2
- ATP2B1 | c.368G>A p.G123D | Missense Mutation (SNP) | VAF 168/455 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53803704; called by muse, mutect2, varscan2
- ATP2B4 | c.160C>A p.L54I | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.112); catalogued as COSV58174232; called by muse, mutect2, varscan2
- ATP2B4 | c.1227C>A p.F409L | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV58174247; called by muse, mutect2, varscan2
- ATP4B | c.558C>T p.I186= | Splice Region (SNP) | VAF 4/9 reads (44%) | catalogued as rs372348110; called by muse, mutect2, varscan2
- ATP5F1A | c.233G>A p.G78D | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV56359388; called by muse, mutect2, varscan2
- ATP5MC3 | c.221A>C p.K74T | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52976036; called by muse, mutect2, varscan2
- ATP5PO | c.515A>C p.K172T | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.345); catalogued as COSV51707917; called by muse, mutect2, varscan2
- ATP6AP2 | c.1039C>T p.R347* (on ENST00000378438; = p.R348* on NM_005765.3) | Nonsense Mutation (SNP) | VAF 37/62 reads (60%) | catalogued as COSV65797151; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1072C>T p.Q358* | Nonsense Mutation (SNP) | VAF 50/142 reads (35%) | catalogued as rs1226218405, CM023020, COSV59472433; called by muse, mutect2, varscan2
- ATP6V1B1 | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs727505222, CM990268, COSV52268223; ClinVar: uncertain significance; called by muse, mutect2
- ATP6V1E1 | c.202A>G p.K68E | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV53656904; called by muse, mutect2, varscan2
- ATP6V1G3 | c.281G>A p.S94N | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs1220595588, COSV55278171; called by muse, mutect2, varscan2
- ATP7B | c.4307A>G p.D1436G | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV54435027; called by muse, mutect2, varscan2
- ATP8A1 | c.1703G>A p.R568Q | Missense Mutation (SNP) | VAF 93/298 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as rs147389955, COSV100046928; called by muse, varscan2
- ATP8A2 | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 82/210 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV54936153; called by muse, mutect2, varscan2
- ATP8A2 | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 75/213 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs535509828, COSV54936164, COSV99680731; called by muse, mutect2, varscan2
- ATP8A2 | c.3350C>T p.A1117V | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0.024); catalogued as rs368163155; called by muse, mutect2, varscan2
- ATP8B1 | c.2711C>T p.A904V | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52172859; called by muse, mutect2, varscan2
- ATP8B2 | c.148C>T p.R50W (on ENST00000672630; = p.R17W on NM_001005855.2) | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs1424511928, COSV59244486; called by muse, mutect2, varscan2
- ATR | c.4806G>T p.E1602D | Missense Mutation (SNP) | VAF 108/273 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV63383724; called by muse, mutect2, varscan2
- ATR | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 43/146 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.106); catalogued as rs532495501, COSV63383731; called by muse, mutect2, varscan2
- ATR | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 19/49 reads (39%) | catalogued as rs1481829794, COSV63383734; called by muse, mutect2, varscan2
- ATRN | c.3952C>T p.R1318* | Nonsense Mutation (SNP) | VAF 33/77 reads (43%) | catalogued as COSV53523748; called by muse, mutect2, varscan2
- ATXN3 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as rs531719156, COSV61493627; called by muse, mutect2, varscan2
- ATXN7L2 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.867); catalogued as rs753760117, COSV63992048; called by muse, mutect2, varscan2
- AUNIP | c.629G>T p.S210I | Missense Mutation (SNP) | VAF 100/212 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.087); catalogued as COSV65352407; called by muse, mutect2, varscan2
- AURKB | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1322292985, COSV60243500; called by muse, mutect2, varscan2
- AVPR1A | c.1174C>T p.R392* | Nonsense Mutation (SNP) | VAF 45/124 reads (36%) | catalogued as rs761842296, COSV54545596; called by muse, mutect2, varscan2
- AXDND1 | c.2790G>T p.E930D | Missense Mutation (SNP) | VAF 66/204 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV62639544; called by muse, mutect2, varscan2
- AXDND1 | c.2853G>T p.E951D | Missense Mutation (SNP) | VAF 176/499 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV62639551; called by muse, varscan2
- AXIN2 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61055422; called by muse, mutect2, varscan2
- B2M | c.349C>T p.R117* | Nonsense Mutation (SNP) | VAF 73/95 reads (77%) | catalogued as COSV62562883; called by muse, mutect2, varscan2
- B3GALT5 | c.449C>T p.A150V | Missense Mutation (SNP) | VAF 75/237 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as rs1252393151, COSV58197816; called by muse, mutect2, varscan2
- B3GLCT | c.367A>G p.R123G | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.245); catalogued as COSV58453205; called by muse, mutect2, varscan2
- B4GALT1 | c.1021A>G p.I341V | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.65); catalogued as COSV65707479; called by muse, mutect2, varscan2
- B4GALT1 | c.702A>C p.E234D | Missense Mutation (SNP) | VAF 33/76 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65707483; called by muse, mutect2, varscan2
- B4GALT2 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs755791825, COSV58842380; called by muse, mutect2, varscan2
- B4GALT2 | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.6); PolyPhen benign (0.363); catalogued as rs752842123, COSV58842392; called by muse, mutect2, varscan2
- B4GALT3 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.348); catalogued as rs1369539144, COSV60526415; called by muse, mutect2, varscan2
- B4GALT6 | c.839T>G p.I280S | Missense Mutation (SNP) | VAF 82/180 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV52702582; called by muse, mutect2, varscan2
- BACE2 | c.772T>G p.L258V | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57737262; called by muse, mutect2, varscan2
- BACH1 | c.540G>T p.Q180H | Missense Mutation (SNP) | VAF 146/336 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV54517243; called by muse, mutect2, varscan2
- BACH2 | c.1696C>A p.L566M | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV57584001; called by muse, mutect2, varscan2
- BAG6 | c.2783A>G p.Q928R (on ENST00000676571; = p.Q881R on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV52987818; called by muse, mutect2, varscan2
- BANK1 | c.357G>T p.K119N | Missense Mutation (SNP) | VAF 94/274 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.211); catalogued as COSV59838766; called by muse, varscan2
- BARX2 | c.102G>T p.E34D | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as COSV55649257; called by muse, mutect2, varscan2
- BAZ1A | c.749A>C p.K250T | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV62408942; called by muse, mutect2, varscan2
- BAZ2A | c.5059A>G p.N1687D | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.1); catalogued as rs757377596, COSV51631362; called by muse, mutect2, varscan2
- BAZ2A | c.4925G>A p.R1642H | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as rs780106566, COSV51631385, COSV51641212; called by muse, mutect2, varscan2
- BAZ2A | c.496G>T p.E166* | Nonsense Mutation (SNP) | VAF 24/66 reads (36%) | catalogued as COSV51631407; called by muse, mutect2, varscan2
- BAZ2B | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 126/339 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.513); catalogued as rs201823989, COSV58595520; called by muse, mutect2, varscan2
- BBOF1 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58220531; called by muse, mutect2
- BBOX1 | c.526T>G p.F176V | Missense Mutation (SNP) | VAF 90/207 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.29); catalogued as COSV54189134; called by muse, varscan2
- BBS12 | c.983C>A p.S328Y | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV58561317, COSV58561950; called by muse, mutect2, varscan2
- BBS2 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 99/258 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762922907, COSV55325032; called by muse, mutect2, varscan2
- BBS4 | c.1106+1G>T p.X369_splice | Splice Site (SNP) | VAF 16/50 reads (32%) | catalogued as COSV51436384; called by muse, mutect2
- BBS7 | c.1008G>T p.Q336H | Missense Mutation (SNP) | VAF 182/528 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV52654186; called by muse, mutect2
- BBS7 | c.358G>T p.D120Y | Missense Mutation (SNP) | VAF 91/246 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV52654200; called by muse, mutect2, varscan2
- BBX | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 54/140 reads (39%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs770138977, COSV57878573; called by muse, mutect2, varscan2
- BCAT1 | c.666G>T p.K222N | Missense Mutation (SNP) | VAF 91/256 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53907318; called by muse, mutect2, varscan2
- BCL10 | c.235C>A p.L79M | Missense Mutation (SNP) | VAF 59/183 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65353458; called by muse, mutect2, varscan2
- BCL11A | c.1991G>A p.R664H (on ENST00000335712 / NM_001365609.1; = p.R698H on NM_018014.4) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs757462932, COSV59624142; called by muse, mutect2, varscan2
- BCL9 | c.1170G>T p.Q390H | Missense Mutation (SNP) | VAF 66/178 reads (37%) | SIFT tolerated (0.64); PolyPhen benign (0.054); catalogued as COSV52340810; called by muse, varscan2
- BCL9 | c.1282G>T p.A428S | Missense Mutation (SNP) | VAF 70/158 reads (44%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV52340821; called by muse, varscan2
- BCLAF1 | c.2660G>T p.W887L | Missense Mutation (SNP) | VAF 207/552 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV50356804; called by muse, varscan2
- BCLAF1 | c.1468G>A p.V490I | Missense Mutation (SNP) | VAF 99/293 reads (34%) | SIFT tolerated (0.58); PolyPhen benign (0.024); catalogued as COSV62143864; called by muse, mutect2, varscan2
- BCLAF1 | c.580G>T p.D194Y | Missense Mutation (SNP) | VAF 39/399 reads (10%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.996); catalogued as rs762741036, COSV62140322, COSV62143069; called by muse, mutect2
- BCO1 | c.1522G>A p.D508N | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (0.79); PolyPhen benign (0.007); catalogued as rs770573150, COSV50727987; called by muse, mutect2, varscan2
- BCOR | c.4639C>T p.R1547* (on ENST00000378444 / NM_001123385.2; = p.R1513* on NM_017745.6) | Nonsense Mutation (SNP) | VAF 14/26 reads (54%) | catalogued as COSV60699371; called by muse, mutect2, varscan2
- BCORL1 | c.3199C>T p.R1067W | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs373106469, COSV54389321; called by muse, mutect2, varscan2
- BDP1 | c.2941G>T p.D981Y | Missense Mutation (SNP) | VAF 112/294 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV62428771; called by muse, mutect2, varscan2
- BDP1 | c.3595G>T p.D1199Y | Missense Mutation (SNP) | VAF 176/429 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV62428776; called by muse, mutect2, varscan2
- BDP1 | c.5278G>T p.D1760Y | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.146); catalogued as COSV62428782; called by muse, varscan2
- BEND5 | c.527C>A p.A176D | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.994); catalogued as COSV100884141, COSV65716375; called by muse, mutect2, varscan2
- BEND7 | c.6A>C p.E2D | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV61987214; called by muse, mutect2, varscan2
- BICDL1 | c.734T>G p.I245S | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as COSV66906922; called by muse, mutect2, varscan2
- BIN2 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV57203545; called by muse, mutect2, varscan2
- BIRC3 | c.832A>C p.S278R | Missense Mutation (SNP) | VAF 113/307 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.119); catalogued as rs1180732396, COSV54814949; called by muse, mutect2, varscan2
- BIRC6 | c.2360A>C p.N787T | Missense Mutation (SNP) | VAF 91/245 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.038); catalogued as COSV70195428; called by muse, mutect2, varscan2
- BIRC6 | c.7789G>A p.A2597T | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs368623523; called by muse, mutect2, varscan2
- BIRC6 | c.9798A>C p.K3266N | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.859); catalogued as COSV70195437; called by muse, mutect2, varscan2
- BIRC6 | c.13323G>T p.K4441N | Missense Mutation (SNP) | VAF 69/175 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV70195442, COSV70208181; called by muse, mutect2, varscan2
- BLID | c.263G>T p.R88I | Missense Mutation (SNP) | VAF 92/264 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.043); catalogued as COSV73340095; called by muse, varscan2
- BLM | c.1939C>A p.L647I | Missense Mutation (SNP) | VAF 53/150 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.122); catalogued as COSV61921664; called by muse, mutect2, varscan2
- BLMH | c.1245C>A p.F415L | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55584230; called by muse, mutect2, varscan2
- BLMH | c.713A>G p.K238R | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55584238; called by muse, mutect2, varscan2
- BLOC1S1 | c.379C>T p.R127W | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV57725112; called by muse, mutect2, varscan2
- BLOC1S6 | c.264G>T p.E88D | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55034904; called by muse, mutect2, varscan2
- BLVRA | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 63/165 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs387906596, CM112102, COSV55512431; called by muse, mutect2, varscan2
- BLZF1 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 99/276 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs138245508; called by muse, mutect2, varscan2
- BMF | c.467A>G p.Q156R | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55018602; called by muse, mutect2
- BMP3 | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 72/153 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs1435451372, COSV51081644; called by muse, mutect2, varscan2
- BMP5 | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 68/204 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs376923719; called by muse, mutect2, varscan2
- BMPR1B | c.1174T>G p.F392V | Missense Mutation (SNP) | VAF 69/164 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs1464900722, COSV52774638; called by muse, mutect2, varscan2
- BMS1 | c.56C>G p.A19G | Missense Mutation (SNP) | VAF 99/245 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV65732831; called by muse, mutect2, varscan2
- BNC1 | c.2917C>T p.R973* | Nonsense Mutation (SNP) | VAF 134/326 reads (41%) | catalogued as rs749980467, COSV61756452, COSV61758671; called by muse, mutect2, varscan2
- BNC1 | c.2195C>A p.A732D | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV61756455; called by muse, mutect2, varscan2
- BNC1 | c.1854T>A p.S618R | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV61756461; called by muse, mutect2, varscan2
- BNC1 | c.1645G>T p.E549* | Nonsense Mutation (SNP) | VAF 51/127 reads (40%) | catalogued as COSV61756465, COSV61757343; called by muse, mutect2, varscan2
- BNC2 | c.3239G>A p.R1080Q | Missense Mutation (SNP) | VAF 64/126 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs772424815, COSV66160640; called by muse, mutect2, varscan2
- BNIP5 | c.1171G>T p.E391* | Nonsense Mutation (SNP) | VAF 33/102 reads (32%) | catalogued as COSV71325271, COSV71325897; called by muse, mutect2, varscan2
- BORCS7 | c.202G>T p.D68Y | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.673); catalogued as COSV54915535; called by muse, mutect2, varscan2
- BPHL | c.793C>T p.H265Y | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as COSV61318720; called by muse, mutect2, varscan2
- BPIFB1 | c.995T>A p.L332Q | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53604983; called by muse, mutect2, varscan2
- BPNT2 | c.917C>G p.A306G | Missense Mutation (SNP) | VAF 63/147 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52906583; called by muse, mutect2, varscan2
- BRCA1 | c.2461G>T p.D821Y | Missense Mutation (SNP) | VAF 217/554 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58783829; called by muse, mutect2, varscan2
- BRCA2 | c.1435G>T p.D479Y | Missense Mutation (SNP) | VAF 86/229 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV66447978; called by muse, mutect2, varscan2
- BRCA2 | c.3575T>G p.F1192C | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.959); catalogued as rs80358606, COSV66447987; ClinVar: conflicting interpretations of pathogenicity / likely benign / benign; called by muse, mutect2, varscan2
- BRCA2 | c.9956C>A p.S3319Y | Missense Mutation (SNP) | VAF 81/221 reads (37%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.462); catalogued as rs778694116, COSV66336667; called by muse, mutect2, varscan2
- BRDT | c.1852C>T p.R618C | Missense Mutation (SNP) | VAF 64/150 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs761603557, COSV62863228; called by muse, varscan2
- BRF2 | c.497C>T p.S166F | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.553); catalogued as rs140725525, COSV55102557; called by muse, mutect2, varscan2
- BRINP1 | c.2098C>T p.R700W | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs541291613, COSV56291761, COSV99774028; called by muse, mutect2, varscan2
- BRINP2 | c.409A>C p.N137H | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); catalogued as COSV64175147; called by muse, mutect2, varscan2
- BRINP3 | c.1901A>G p.K634R | Missense Mutation (SNP) | VAF 140/399 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100819184, COSV66513164; called by muse, mutect2, varscan2
- BROX | c.881C>T p.T294I | Missense Mutation (SNP) | VAF 84/272 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.145); catalogued as COSV61798868; called by muse, mutect2, varscan2
- BRPF1 | c.2582C>T p.A861V | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.012); catalogued as COSV57403136; called by muse, mutect2, varscan2
- BSN | c.5092C>A p.L1698I | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.723); catalogued as COSV56512845, COSV56516394; called by muse, mutect2
- BSN | c.5213C>T p.S1738L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs1476028541, COSV56512854; called by muse, mutect2, varscan2
- BTAF1 | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as rs1313990753, COSV56429702; called by muse, mutect2, varscan2
- BTAF1 | c.1034G>T p.R345I | Missense Mutation (SNP) | VAF 96/277 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56429757, COSV99796027; called by muse, mutect2, varscan2
- BTBD7 | c.2071C>T p.R691* | Nonsense Mutation (SNP) | VAF 25/79 reads (32%) | catalogued as rs1198567556, COSV100597941, COSV58283311; called by muse, mutect2, varscan2
- BTBD7 | c.1307C>T p.S436L | Missense Mutation (SNP) | VAF 64/158 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs780909487, COSV58283320; called by muse, mutect2, varscan2
- BTBD9 | c.1232A>G p.N411S | Missense Mutation (SNP) | VAF 73/200 reads (37%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as COSV58420665; called by muse, mutect2, varscan2
- BTN1A1 | c.1341C>A p.F447L | Missense Mutation (SNP) | VAF 62/171 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV55066481; called by muse, mutect2, varscan2
- BTN2A2 | c.742G>A p.A248T | Missense Mutation (SNP) | VAF 85/235 reads (36%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as rs780217318, COSV61856569; called by muse, mutect2, varscan2
- BTNL2 | c.600C>A p.F200L | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV66630147; called by muse, mutect2, varscan2
- BUB1 | c.1132A>G p.T378A | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs752483610, COSV57061138; called by muse, mutect2, varscan2
- BUD13 | c.891G>T p.K297N | Missense Mutation (SNP) | VAF 100/283 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV52766898, COSV52767913; called by muse, mutect2, varscan2
- C10orf90 | c.2007A>C p.Q669H | Missense Mutation (SNP) | VAF 71/188 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52949247; called by muse, mutect2, varscan2
- C11orf71 | c.251G>A p.S84N | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.031); catalogued as COSV57783903; called by muse, mutect2, varscan2
- C12orf4 | c.763G>T p.E255* | Nonsense Mutation (SNP) | VAF 58/171 reads (34%) | catalogued as COSV54205561; called by muse, mutect2, varscan2
- C12orf4 | c.708C>A p.N236K | Missense Mutation (SNP) | VAF 146/403 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as COSV54205569; called by mutect2, varscan2
- C14orf39 | c.32G>A p.R11K | Missense Mutation (SNP) | VAF 72/205 reads (35%) | SIFT tolerated (0.65); PolyPhen benign (0.146); catalogued as COSV58779370; called by muse, mutect2, varscan2
- C16orf87 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 79/218 reads (36%) | catalogued as COSV53511528; called by muse, mutect2, varscan2
- C17orf75 | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56752187; called by muse, mutect2, varscan2
- C1GALT1C1L | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 84/205 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as rs910474337, COSV56749520; called by muse, mutect2, varscan2
- C1QTNF1 | c.639G>T p.K213N | Missense Mutation (SNP) | VAF 47/126 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.653); catalogued as COSV59260426; called by muse, mutect2, varscan2
- C1QTNF3 | c.661C>T p.R221* | Nonsense Mutation (SNP) | VAF 71/156 reads (46%) | catalogued as rs1173584671, COSV51467655; called by muse, mutect2, varscan2
- C1orf141 | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs147612243; called by muse, mutect2, varscan2
- C1orf174 | c.594C>A p.F198L | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64365621; called by muse, mutect2, varscan2
- C1orf189 | c.113C>A p.A38E | Missense Mutation (SNP) | VAF 138/374 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV63890751; called by muse, mutect2, varscan2
- C1orf194 | c.337G>T p.E113* (on ENST00000369948 / NM_001245025.3; = p.E101* on NM_001122961.2 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 65/176 reads (37%) | catalogued as rs763816794, COSV64049816; called by muse, mutect2, varscan2
- C1orf52 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs750091650, COSV53998001; called by muse, mutect2, varscan2
- C20orf194 | c.3442G>T p.D1148Y | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52691097; called by muse, mutect2, varscan2
- C20orf194 | c.3393C>A p.F1131L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.979); catalogued as COSV52691108; called by muse, mutect2, varscan2
- C20orf194 | c.1632A>T p.E544D | Missense Mutation (SNP) | VAF 96/250 reads (38%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as COSV52691137; called by muse, mutect2, varscan2
- C20orf194 | c.590G>A p.G197E | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1219238028, COSV52691168; called by muse, mutect2, varscan2
- C22orf23 | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 7/33 reads (21%) | catalogued as COSV50777637; called by muse, mutect2
- C2CD3 | c.4356G>T p.K1452N | Missense Mutation (SNP) | VAF 80/219 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as COSV58089347, COSV58101865; called by muse, mutect2, varscan2
- C2CD3 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 102/269 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.034); catalogued as rs767466509, COSV100486163, COSV58089358; called by muse, mutect2, varscan2
- C2CD5 | c.2881C>A p.L961I | Missense Mutation (SNP) | VAF 141/347 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV61722705; called by muse, mutect2, varscan2
- C2CD5 | c.2434T>G p.S812A | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV61722712; called by muse, mutect2, varscan2
- C2CD5 | c.2333C>A p.S778Y | Missense Mutation (SNP) | VAF 58/200 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.084); catalogued as COSV61722721; called by muse, mutect2, varscan2
- C2orf16 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 35/129 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV68645327, COSV68645593; called by muse, mutect2, varscan2
- C2orf16 | c.1924G>T p.E642* | Nonsense Mutation (SNP) | VAF 58/145 reads (40%) | catalogued as COSV62673687; called by muse, mutect2, varscan2
- C2orf16 | c.5123G>T p.R1708I | Missense Mutation (SNP) | VAF 127/319 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as COSV62673693, COSV62675606; called by muse, mutect2, varscan2
- C2orf69 | c.1022G>T p.R341I | Missense Mutation (SNP) | VAF 57/192 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60665702, COSV60667349; called by muse, mutect2, varscan2
- C2orf80 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as rs987661802, COSV58015332; called by muse, mutect2, varscan2
- C2orf88 | c.21G>T p.K7N | Missense Mutation (SNP) | VAF 122/308 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61409642; called by muse, mutect2, varscan2
- C3 | c.4398C>A p.Y1466* | Nonsense Mutation (SNP) | VAF 31/81 reads (38%) | catalogued as COSV55568459; called by muse, mutect2, varscan2
- C3 | c.3490-1G>T p.X1164_splice | Splice Site (SNP) | VAF 52/151 reads (34%) | catalogued as COSV55568470; called by muse, mutect2, varscan2
- C3 | c.1758G>T p.E586D | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV55568495; called by muse, mutect2
- C3orf20 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 65/194 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.343); catalogued as rs768861528, COSV53782331, COSV99513234; called by muse, mutect2, varscan2
- C4orf50 | c.430A>G p.K144E (on ENST00000324058; = p.K1376E on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60687392; called by muse, mutect2
- C5 | c.2819C>A p.S940Y | Missense Mutation (SNP) | VAF 193/490 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV56323882; called by muse, mutect2, varscan2
- C6 | c.1751C>T p.S584L | Missense Mutation (SNP) | VAF 74/203 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.411); catalogued as rs763257632, COSV54704717; called by muse, mutect2, varscan2
- C6 | c.496G>T p.D166Y | Missense Mutation (SNP) | VAF 111/294 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54704728; called by muse, mutect2, varscan2
- C7orf25 | c.1199T>G p.L400R | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63273104, COSV63274413; called by muse, mutect2, varscan2
- C8A | c.1111G>T p.D371Y | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.663); catalogued as COSV63483049; called by muse, mutect2, varscan2
- C8orf34 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 75/156 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV61370540; called by muse, mutect2, varscan2
- C8orf34 | c.1326C>T p.F442= | Splice Region (SNP) | VAF 182/243 reads (75%) | catalogued as rs201463505, COSV57396967; called by muse, mutect2, varscan2
- C8orf34 | c.1342A>G p.T448A | Missense Mutation (SNP) | VAF 63/164 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.046); catalogued as COSV57396985; called by muse, mutect2, varscan2
- C9orf131 | c.1519C>T p.L507F | Missense Mutation (SNP) | VAF 174/421 reads (41%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.965); catalogued as rs896724676, COSV56609553; called by muse, mutect2, varscan2
- C9orf43 | c.726G>T p.K242N | Missense Mutation (SNP) | VAF 103/264 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV55911752; called by muse, mutect2, varscan2
- C9orf43 | c.915G>T p.K305N | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs1356197164, COSV55911760; called by muse, mutect2, varscan2
- C9orf64 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as COSV59032087; called by muse, mutect2, varscan2
- CA11 | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.391); catalogued as COSV50032723; called by muse, mutect2, varscan2
- CA4 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs373844529; called by muse, mutect2
- CAB39L | c.642G>T p.E214D | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV61713482; called by muse, mutect2, varscan2
- CABYR | c.751G>T p.E251* | Nonsense Mutation (SNP) | VAF 33/87 reads (38%) | catalogued as COSV59110151; called by muse, mutect2, varscan2
- CACHD1 | c.460C>T p.R154* | Nonsense Mutation (SNP) | VAF 48/132 reads (36%) | catalogued as rs761819776, COSV51547949; called by muse, mutect2, varscan2
- CACNA1A | c.2138C>A p.A713D | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV64189409; called by muse, mutect2
- CACNA1B | c.5227C>T p.R1743C | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs370345897; called by muse, mutect2
- CACNA1C | c.2617C>T p.P873S | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV59696125; called by muse, mutect2, varscan2
- CACNA1D | c.5609G>T p.R1870I (on ENST00000350061 / NM_001128840.3; = p.R1890I on NM_000720.4) | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.024); catalogued as COSV55437170; called by muse, mutect2, varscan2
- CACNA1E | c.1375C>T p.R459W | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as rs1458093500, COSV62398100, COSV62413841; called by muse, varscan2
- CACNA1E | c.3749A>C p.D1250A | Missense Mutation (SNP) | VAF 66/184 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV62381864; called by muse, mutect2, varscan2
- CACNA2D3 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.85); catalogued as rs764440125, COSV55512686; called by muse, mutect2, varscan2
- CACNB3 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs758647170, COSV56397086; called by muse, mutect2, varscan2
- CACNG3 | c.793T>G p.F265V | Missense Mutation (SNP) | VAF 102/249 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV50064009; called by muse, mutect2, varscan2
- CAD | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV53023446; called by muse, varscan2
- CAD | c.6437G>A p.R2146Q | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs377103397, COSV53023457; called by muse, mutect2, varscan2
- CADM1 | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 61/148 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs758008656, COSV59002787; called by muse, mutect2, varscan2
- CADM3 | c.274G>A p.E92K (on ENST00000368125 / NM_001127173.3; = p.E126K on NM_021189.5) | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs888060211, COSV63683587; called by muse, mutect2, varscan2
- CADPS | c.2557C>A p.L853I | Missense Mutation (SNP) | VAF 75/216 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.015); catalogued as COSV51866506; called by muse, mutect2, varscan2
- CADPS | c.1519G>T p.D507Y | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51866519; called by muse, mutect2, varscan2
- CADPS | c.1004T>C p.M335T | Missense Mutation (SNP) | VAF 51/155 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV51866539; called by muse, mutect2, varscan2
- CALCR | c.739G>C p.A247P (on ENST00000649521 / NM_001164737.2; = p.A231P on NM_001742.4) | Missense Mutation (SNP) | VAF 91/238 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.308); catalogued as COSV100810891, COSV64005728; called by muse, mutect2, varscan2
- CALN1 | c.372G>T p.W124C (on ENST00000329008 / NM_001017440.3; = p.W166C on NM_031468.4) | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV61119278; called by muse, mutect2, varscan2
- CALR3 | c.269C>T p.T90I | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV54168331; called by muse, mutect2, varscan2
- CAMK4 | c.431C>T p.A144V | Missense Mutation (SNP) | VAF 93/293 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.336); catalogued as COSV56661893; called by muse, mutect2, varscan2
- CAMSAP1 | c.4635G>T p.K1545N | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1434079607, COSV56718292, COSV56721079; called by muse, mutect2
- CAMTA2 | c.1145A>G p.N382S | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.952); catalogued as COSV61832945; called by muse, mutect2, varscan2
- CAND1 | c.1472C>T p.S491L | Missense Mutation (SNP) | VAF 116/356 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1389034178, COSV73389520; called by muse, mutect2, varscan2
- CAND2 | c.3308G>T p.G1103V (on ENST00000456430 / NM_001162499.2; = p.G986V on NM_012298.3) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV55986596; called by muse, mutect2, varscan2
- CAPN2 | c.1537G>A p.D513N | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.177); catalogued as rs369320951, COSV54333957; called by muse, mutect2, varscan2
- CAPN3 | c.10G>A p.V4I | Missense Mutation (SNP) | VAF 75/174 reads (43%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.033); catalogued as rs140660066, CM990294; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAPN5 | c.712G>A p.D238N (on ENST00000456580; = p.D198N on NM_004055.5) | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.036); catalogued as rs782492041, COSV53685541; called by muse, mutect2, varscan2
- CAPRIN2 | c.1996G>T p.E666* | Nonsense Mutation (SNP) | VAF 98/253 reads (39%) | catalogued as COSV51830332; called by muse, mutect2, varscan2
- CAPRIN2 | c.889A>G p.T297A | Missense Mutation (SNP) | VAF 43/119 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV51830341; called by muse, mutect2, varscan2
- CAPSL | c.315+1G>T p.X105_splice | Splice Site (SNP) | VAF 75/202 reads (37%) | catalogued as COSV68437116; called by muse, mutect2, varscan2
- CARD6 | c.1376G>A p.R459H | Missense Mutation (SNP) | VAF 92/255 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.216); catalogued as rs199835164, COSV54564127; called by muse, mutect2, varscan2
- CARMIL1 | c.583A>C p.N195H | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61513505; called by muse, mutect2, varscan2
- CARMIL1 | c.3693G>T p.K1231N | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.482); catalogued as COSV61513515; called by muse, mutect2, varscan2
- CARNMT1 | c.812G>A p.R271Q | Missense Mutation (SNP) | VAF 69/181 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.082); catalogued as rs1389888862, COSV65193036; called by muse, mutect2, varscan2
- CARS1 | c.2042C>T p.A681V | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as COSV53449821; called by muse, mutect2, varscan2
- CASD1 | c.1529G>A p.R510Q | Missense Mutation (SNP) | VAF 72/199 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs774485536, COSV51970560; called by muse, mutect2
- CASP10 | c.1437G>T p.K479N | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.223); catalogued as COSV51845105; called by muse, mutect2, varscan2
- CASP2 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as rs144817015, COSV100131376; called by muse, mutect2, varscan2
- CASP3 | c.268G>T p.D90Y | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57724572; called by muse, mutect2, varscan2
- CASP8AP2 | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as rs753052099, COSV52745086, COSV99386833; called by muse, mutect2, varscan2
- CASP8AP2 | c.5851T>G p.F1951V | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52745093; called by muse, mutect2, varscan2
- CASQ1 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1207492312, COSV63624188; called by muse, varscan2
- CATSPER3 | c.161T>G p.I54R | Missense Mutation (SNP) | VAF 68/190 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.466); catalogued as COSV50945207; called by muse, mutect2, varscan2
- CATSPERB | c.3017C>T p.A1006V | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV56422085; called by muse, varscan2
- CATSPERE | c.1042A>T p.R348* | Nonsense Mutation (SNP) | VAF 97/284 reads (34%) | catalogued as COSV63675766; called by muse, mutect2, varscan2
- CATSPERE | c.2428A>G p.T810A | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV63675772; called by muse, mutect2, varscan2
- CATSPERG | c.2557-1G>T p.X853_splice | Splice Site (SNP) | VAF 26/78 reads (33%) | catalogued as COSV53045725; called by muse, mutect2, varscan2
- CATSPERG | c.2737A>G p.N913D | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53045731; called by muse, mutect2
- CAVIN4 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 95/384 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.039); catalogued as rs369545613, COSV56866500; called by muse, mutect2, varscan2
- CBL | c.1676G>A p.R559Q | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.778); catalogued as rs143034856; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CBLN1 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54653318; called by muse, mutect2
- CBWD3 | c.1066C>T p.R356* | Nonsense Mutation (SNP) | VAF 31/195 reads (16%) | catalogued as rs1554669939; called by muse, mutect2, varscan2
- CBX8 | c.1166G>T p.R389I | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53935364; called by muse, mutect2, varscan2
- CC2D2A | c.2513C>A p.S838* | Nonsense Mutation (SNP) | VAF 29/71 reads (41%) | catalogued as COSV67502165; called by muse, mutect2, varscan2
- CCDC102B | c.514G>T p.D172Y | Missense Mutation (SNP) | VAF 107/273 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV100102486, COSV60134247; called by muse, mutect2, varscan2
- CCDC110 | c.1952C>A p.S651Y | Missense Mutation (SNP) | VAF 81/219 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.748); catalogued as COSV56869259; called by muse, mutect2, varscan2
- CCDC110 | c.1708G>T p.E570* | Nonsense Mutation (SNP) | VAF 65/165 reads (39%) | catalogued as COSV56869274; called by muse, mutect2, varscan2
- CCDC110 | c.1190G>A p.R397K | Missense Mutation (SNP) | VAF 91/245 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56869286; called by muse, mutect2, varscan2
- CCDC110 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs201279686, COSV56873556; called by muse, varscan2
- CCDC110 | c.585G>T p.K195N | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.974); catalogued as COSV56872383; called by muse, varscan2
- CCDC116 | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758808128, COSV53037115; called by muse, mutect2, varscan2
- CCDC117 | c.590T>G p.M197R | Missense Mutation (SNP) | VAF 48/129 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as COSV50770559; called by muse, mutect2, varscan2
- CCDC125 | c.1477G>T p.D493Y | Missense Mutation (SNP) | VAF 74/187 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.667); catalogued as COSV67287589; called by muse, mutect2, varscan2
- CCDC125 | c.75A>C p.E25D | Missense Mutation (SNP) | VAF 73/171 reads (43%) | SIFT tolerated (0.96); PolyPhen benign (0.015); catalogued as COSV67287592; called by muse, mutect2, varscan2
- CCDC126 | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.031); catalogued as rs146283363; called by muse, mutect2
- CCDC127 | c.485T>C p.F162S | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.099); catalogued as COSV57256102; called by muse, mutect2, varscan2
- CCDC141 | c.3796C>A p.L1266I | Missense Mutation (SNP) | VAF 72/184 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.073); catalogued as COSV55383368; called by muse, varscan2
- CCDC141 | c.1987C>A p.L663I | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV55368573; called by muse, mutect2, varscan2
- CCDC148 | c.1580T>G p.F527C | Missense Mutation (SNP) | VAF 56/157 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV51754093; called by muse, mutect2, varscan2
- CCDC15 | c.2397G>T p.K799N | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as rs764907206, COSV61080185; called by muse, mutect2, varscan2
- CCDC151 | c.329C>A p.T110N | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV52950251; called by muse, mutect2, varscan2
- CCDC158 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 48/127 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV66355154; called by muse, mutect2, varscan2
- CCDC160 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.74); catalogued as COSV66251316; called by muse, mutect2, varscan2
- CCDC17 | c.1516C>A p.L506I | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV59645728; called by muse, mutect2, varscan2
- CCDC171 | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 97/129 reads (75%) | catalogued as COSV52633899; called by muse, mutect2, varscan2
- CCDC171 | c.3285G>T p.K1095N | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV52633906; called by muse, mutect2, varscan2
- CCDC173 | c.888G>T p.K296N | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV71428556; called by muse, mutect2, varscan2
- CCDC173 | c.179A>C p.D60A | Missense Mutation (SNP) | VAF 84/220 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as COSV69572484; called by muse, mutect2, varscan2
- CCDC174 | c.804G>T p.E268D | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV57979797; called by muse, mutect2, varscan2
- CCDC178 | c.1450T>G p.L484V | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as COSV55758733; called by muse, mutect2
- CCDC18 | c.1049A>C p.K350T | Missense Mutation (SNP) | VAF 119/316 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV58141130; called by muse, mutect2, varscan2
- CCDC18 | c.2980G>T p.E994* (on ENST00000343253 / NM_001306076.1; = p.E995* on NM_206886.4) | Nonsense Mutation (SNP) | VAF 128/311 reads (41%) | catalogued as COSV58141139; called by muse, mutect2, varscan2
- CCDC186 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 154/410 reads (38%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as rs532080412, COSV100990995, COSV65159686; called by muse, varscan2
- CCDC191 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 119/295 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs778514406, COSV55670023; called by muse, mutect2, varscan2
- CCDC198 | c.299G>T p.R100I | Missense Mutation (SNP) | VAF 112/327 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53601250; called by muse, mutect2, varscan2
7,187 further variants in this file (5,495 protein-altering or splice-affecting, 1,520 silent, 172 other) are not listed here.
